Somatic mutation profile of tumor specimen TCGA-AA-3845-01A (aliquot TCGA-AA-3845-01A-01W-0995-10) from TCGA case TCGA-AA-3845, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Ascending colon; AJCC pathologic stage: Stage IIA; Age at diagnosis: 86.5 years (31,593 days).
Specimen TCGA-AA-3845-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 448c3c97-e16c-4391-83f6-a83c50af832e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AA-3845-10A (Blood Derived Normal), aliquot TCGA-AA-3845-10A-01W-0995-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/153fa53b-0476-40cb-9bce-21f529c0ea8d

The open-access MAF lists 1,087 somatic variants for this specimen: 834 protein-altering or splice-affecting, 232 silent, 21 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 578, Silent 232, Frame Shift Del 156, Nonsense Mutation 35, Frame Shift Ins 24, In Frame Del 15, Splice Site 14, Splice Region 11, Intron 9, 3'UTR 6, RNA 3, Nonstop Mutation 1.

Variants (750 of 1,087; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ALG6 | c.1194del p.F398Lfs*2 | Frame Shift Del (DEL) | VAF 182/791 reads (23%) | catalogued as rs1207096732; ClinVar: likely pathogenic; called by mutect2, pindel, varscan2
- ASPM | c.5149del p.I1717* | Frame Shift Del (DEL) | VAF 30/95 reads (32%) | catalogued as rs199422167, CD077387; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- ETV6 | c.1105C>T p.R369W | Missense Mutation (SNP) | VAF 167/439 reads (38%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM1511682, COSV56765384, COSV56765583; called by muse, mutect2, varscan2
- FERMT1 | c.676del p.Q226Sfs*26 | Frame Shift Del (DEL) | VAF 115/507 reads (23%) | catalogued as rs748240859, COSV54090339; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- KANSL1 | c.779del p.G260Vfs*19 | Frame Shift Del (DEL) | VAF 48/185 reads (26%) | catalogued as rs748018297; ClinVar: uncertain significance / pathogenic; called by mutect2, pindel, varscan2
- KLHL40 | c.1405G>T p.G469C | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs367579275, CM136546; ClinVar: pathogenic; called by muse, varscan2
- KRAS | c.181C>A p.Q61K | Missense Mutation (SNP) | VAF 83/202 reads (41%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen benign (0.083); catalogued as rs121913238, COSV55502066, COSV55502677; ClinVar: pathogenic; called by muse, mutect2, varscan2
- LARP7 | c.1213del p.T405Qfs*5 | Frame Shift Del (DEL) | VAF 22/96 reads (23%) | catalogued as rs750946801; ClinVar: likely pathogenic; called by mutect2, varscan2
- PIGO | c.2361del p.T788Lfs*25 | Frame Shift Del (DEL) | VAF 12/42 reads (29%) | catalogued as rs770591449, COSV99956719; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- POLR3GL | c.326-1G>A p.X109_splice | Splice Site (SNP) | VAF 46/156 reads (29%) | catalogued as rs1553763618, COSV100996784; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- SLC18A2 | c.711del p.F238Sfs*48 | Frame Shift Del (DEL) | VAF 89/299 reads (30%) | catalogued as rs762879329, COSV53693545; ClinVar: likely pathogenic; called by mutect2, pindel
- SMAD4 | c.1598T>G p.L533R | Missense Mutation (SNP) | VAF 119/443 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs377767382, CM040451, CM100521, COSV61684983, COSV61685664; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TTN | c.59765del p.P19922Lfs*10 (on ENST00000591111; = p.P12498Lfs*10 on NM_003319.4) | Frame Shift Del (DEL) | VAF 6/30 reads (20%) | catalogued as rs774395395, COSV99045840; ClinVar: uncertain significance / likely pathogenic / pathogenic; called by pindel, varscan2
- VHL | c.444del p.F148Lfs*11 | Frame Shift Del (DEL) | VAF 47/256 reads (18%) | catalogued as rs869025653, CM982009; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- A2ML1 | c.1624A>G p.S542G | Missense Mutation (SNP) | VAF 251/1601 reads (16%) | SIFT tolerated (0.55); PolyPhen benign (0.042); catalogued as COSV100228866; called by muse, mutect2, varscan2
- ABAT | c.331G>A p.A111T | Missense Mutation (SNP) | VAF 70/278 reads (25%) | SIFT tolerated (0.33); PolyPhen benign (0.045); catalogued as rs150783272; called by muse, mutect2, varscan2
- ABCA6 | c.4817T>C p.M1606T | Missense Mutation (SNP) | VAF 464/1951 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.028); catalogued as rs751793678, COSV99446348; called by muse, mutect2, varscan2
- ABHD6 | c.700G>A p.D234N | Missense Mutation (SNP) | VAF 140/572 reads (24%) | SIFT tolerated (0.33); PolyPhen benign (0.439); catalogued as COSV99917008; called by muse, mutect2, varscan2
- ABLIM2 | c.1405del p.D469Mfs*94 (on ENST00000341937 / NM_001130084.2; = p.D418Mfs*55 on NM_032432.5) | Frame Shift Del (DEL) | VAF 34/149 reads (23%) | catalogued as COSV56411246; called by mutect2, pindel, varscan2
- ABLIM2 | c.962C>T p.A321V | Missense Mutation (SNP) | VAF 36/132 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99589535; called by muse, mutect2, varscan2
- ACKR2 | c.523G>A p.V175I | Missense Mutation (SNP) | VAF 54/201 reads (27%) | SIFT tolerated (0.49); PolyPhen benign (0.005); catalogued as rs748142680, COSV99825494; called by muse, mutect2, varscan2
- ACSL3 | c.689G>A p.R230H | Missense Mutation (SNP) | VAF 208/1419 reads (15%) | SIFT tolerated (0.08); PolyPhen benign (0.013); catalogued as rs748604442, COSV100657925; called by muse, mutect2, varscan2
- ACVR2A | c.1080T>C p.V360= | Splice Region (SNP) | VAF 93/368 reads (25%) | catalogued as COSV99604412; called by muse, mutect2, varscan2
- ADAM18 | c.1462G>T p.A488S | Missense Mutation (SNP) | VAF 251/837 reads (30%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.53); catalogued as COSV99695460; called by muse, mutect2, varscan2
- ADAMTS2 | c.3268T>C p.C1090R | Missense Mutation (SNP) | VAF 38/143 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99281955; called by muse, mutect2, varscan2
- ADAMTS20 | c.4913C>A p.P1638H | Missense Mutation (SNP) | VAF 211/1363 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101239197, COSV67141911; called by muse, mutect2, varscan2
- ADAMTS20 | c.943C>T p.R315C | Missense Mutation (SNP) | VAF 160/781 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.001); catalogued as rs765553839, COSV101239198; called by muse, mutect2, varscan2
- ADCK1 | c.1400+2T>C p.X467_splice | Splice Site (SNP) | VAF 27/80 reads (34%) | catalogued as COSV99451582; called by muse, mutect2, varscan2
- ADCY2 | c.1412G>T p.R471L | Missense Mutation (SNP) | VAF 14/61 reads (23%) | SIFT tolerated (0.3); PolyPhen benign (0.007); catalogued as COSV100602683; called by muse, mutect2, varscan2
- AFF3 | c.2987A>G p.E996G | Missense Mutation (SNP) | VAF 112/400 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100418692; called by muse, mutect2, varscan2
- AGO2 | c.2063G>A p.R688H | Missense Mutation (SNP) | VAF 23/56 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99595649; called by muse, mutect2, varscan2
- AHNAK2 | c.341C>T p.T114M | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.742); catalogued as rs200025024, COSV60917709; called by muse, mutect2, varscan2
- AIPL1 | c.88G>A p.G30R | Missense Mutation (SNP) | VAF 34/100 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs145112457, COSV100006040; called by muse, varscan2
- AK7 | c.472T>C p.W158R | Missense Mutation (SNP) | VAF 35/209 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99967219; called by muse, mutect2, varscan2
- AKAP10 | c.1401G>T p.R467S | Missense Mutation (SNP) | VAF 46/324 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV99855413; called by muse, mutect2, varscan2
- ALDH18A1 | c.1367G>A p.R456H | Missense Mutation (SNP) | VAF 33/87 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as rs760865106, COSV64662802; called by muse, mutect2, varscan2
- ALDH8A1 | c.149C>T p.A50V | Missense Mutation (SNP) | VAF 21/70 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs755934699, COSV99664666; called by muse, mutect2, varscan2
- ALDOB | c.482G>T p.S161I | Missense Mutation (SNP) | VAF 30/104 reads (29%) | SIFT tolerated (0.18); PolyPhen benign (0.095); catalogued as COSV100878854; called by muse, mutect2, varscan2
- ALK | c.1647G>T p.E549D | Missense Mutation (SNP) | VAF 90/255 reads (35%) | SIFT tolerated (0.08); PolyPhen benign (0.396); catalogued as COSV101201896; called by muse, mutect2, varscan2
- ALMS1 | c.12114G>T p.Q4038H | Missense Mutation (SNP) | VAF 32/106 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100042226; called by muse, mutect2, varscan2
- ALPK3 | c.4441T>C p.Y1481H | Missense Mutation (SNP) | VAF 10/51 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99360778; called by muse, mutect2, varscan2
- ALS2 | c.4808C>T p.P1603L | Missense Mutation (SNP) | VAF 60/250 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99968734, COSV99969217; called by muse, mutect2, varscan2
- ANKRD44 | c.1919C>A p.A640D | Missense Mutation (SNP) | VAF 54/151 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as COSV99984858; called by muse, mutect2, varscan2
- ANKRD45 | c.284C>A p.A95D | Missense Mutation (SNP) | VAF 30/111 reads (27%) | SIFT tolerated (0.23); PolyPhen benign (0.038); catalogued as COSV100322475; called by muse, mutect2, varscan2
- ANPEP | c.2098A>C p.S700R | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT tolerated (0.64); PolyPhen benign (0.006); catalogued as COSV100262984; called by muse, mutect2, varscan2
- ANTXR1 | c.938C>T p.T313I | Missense Mutation (SNP) | VAF 38/183 reads (21%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.933); catalogued as COSV58015869; called by muse, mutect2, varscan2
- APMAP | c.971G>A p.R324H | Missense Mutation (SNP) | VAF 10/64 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs181867455, COSV99468412; called by muse, varscan2
- APPL1 | c.428C>T p.A143V | Missense Mutation (SNP) | VAF 140/558 reads (25%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.568); catalogued as rs753038546, COSV55700704; called by muse, varscan2
- ARAP2 | c.3309G>A p.W1103* | Nonsense Mutation (SNP) | VAF 416/1380 reads (30%) | catalogued as rs866438657, COSV100394548; called by muse, mutect2, varscan2
- ARHGAP24 | c.1037A>T p.N346I (on ENST00000395184 / NM_001025616.3; = p.N253I on NM_031305.3) | Missense Mutation (SNP) | VAF 27/80 reads (34%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.564); catalogued as COSV99982034; called by muse, mutect2, varscan2
- ARHGAP31 | c.2521C>A p.P841T | Missense Mutation (SNP) | VAF 39/150 reads (26%) | SIFT tolerated, low confidence (0.38); PolyPhen benign (0); catalogued as COSV99957009; called by muse, mutect2, varscan2
- ARHGAP5 | c.688C>T p.R230* | Nonsense Mutation (SNP) | VAF 17/62 reads (27%) | catalogued as rs765717212, COSV100565239; called by muse, mutect2, varscan2
- ARHGEF2 | c.640G>A p.A214T (on ENST00000361247 / NM_001162383.2; = p.A186T on NM_004723.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 29/95 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV100560502; called by muse, mutect2, varscan2
- ARID2 | c.109del p.I37Sfs*21 | Frame Shift Del (DEL) | VAF 4/26 reads (15%) | catalogued as COSV57601825; called by pindel, varscan2
- ARL11 | c.80C>T p.T27M | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.697); catalogued as rs1394373519, COSV56290674; called by muse, mutect2, varscan2
- ARMC3 | c.2085G>T p.E695D | Missense Mutation (SNP) | VAF 74/1111 reads (7%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.565); catalogued as COSV99957960; called by muse, mutect2
- ARMC4 | c.3095G>A p.R1032H | Missense Mutation (SNP) | VAF 78/195 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs375622560; called by muse, mutect2, varscan2
- ARMC4 | c.2720A>G p.N907S | Missense Mutation (SNP) | VAF 167/944 reads (18%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.468); catalogued as COSV100536690; called by muse, mutect2, varscan2
- ARPC5 | c.250A>G p.I84V | Missense Mutation (SNP) | VAF 14/48 reads (29%) | SIFT tolerated (0.44); PolyPhen benign (0.007); catalogued as COSV99664781; called by muse, mutect2, varscan2
- ARRDC1 | c.211C>A p.L71M | Missense Mutation (SNP) | VAF 12/62 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.964); catalogued as COSV101004533; called by muse, mutect2, varscan2
- AS3MT | c.425C>T p.A142V | Missense Mutation (SNP) | VAF 53/220 reads (24%) | SIFT tolerated (0.09); PolyPhen benign (0.113); catalogued as COSV100185686; called by muse, mutect2, varscan2
- ASIC2 | c.555+1G>A p.X185_splice | Splice Site (SNP) | VAF 15/86 reads (17%) | catalogued as COSV100726275; called by muse, mutect2, varscan2
- ASPN | c.201del p.P68Hfs*24 | Frame Shift Del (DEL) | VAF 53/223 reads (24%) | catalogued as rs778526424; called by mutect2, pindel, varscan2
- ASPSCR1 | c.422C>T p.T141M | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs769048147, COSV60729533; called by muse, varscan2
- ATF7IP2 | c.635A>G p.K212R | Missense Mutation (SNP) | VAF 24/81 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.725); catalogued as COSV100202599; called by muse, mutect2, varscan2
- ATG2B | c.5960T>C p.V1987A | Missense Mutation (SNP) | VAF 14/380 reads (4%) | SIFT tolerated (1); PolyPhen probably damaging (0.996); catalogued as COSV99952030; called by muse, mutect2
- ATP10B | c.3142G>A p.V1048I | Missense Mutation (SNP) | VAF 50/218 reads (23%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.67); catalogued as rs540605471, COSV100514791; called by muse, mutect2, varscan2
- ATP1A4 | c.1048-1G>A p.X350_splice | Splice Site (SNP) | VAF 23/78 reads (29%) | catalogued as COSV100927524, COSV100927649; called by muse, mutect2, varscan2
- ATP2B2 | c.2551G>A p.V851I (on ENST00000352432; = p.V817I on NM_001683.5) | Missense Mutation (SNP) | VAF 20/74 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs778120026, COSV59492636; called by muse, mutect2, varscan2
- BCL2L1 | c.647C>T p.T216M (on ENST00000307677 / NM_001317919.2; = p.T153M on NM_001191.4) | Missense Mutation (SNP) | VAF 38/84 reads (45%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.622); catalogued as rs1447088802, COSV56967574; called by muse, mutect2, varscan2
- BCR | c.2993T>C p.M998T | Missense Mutation (SNP) | VAF 7/20 reads (35%) | SIFT deleterious (0.05); PolyPhen benign (0.388); catalogued as COSV100006394; called by muse, mutect2, varscan2
- BMP10 | c.1034C>A p.P345H | Missense Mutation (SNP) | VAF 82/461 reads (18%) | SIFT tolerated (0.23); PolyPhen benign (0.432); catalogued as COSV99770386; called by muse, mutect2, varscan2
- BOC | c.2581G>A p.V861I | Missense Mutation (SNP) | VAF 78/260 reads (30%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.997); catalogued as rs148702312; called by muse, mutect2, varscan2
- BRD1 | c.2884G>A p.V962I (on ENST00000216267 / NM_001349940.1; = p.V1093I on NM_001304808.3) | Missense Mutation (SNP) | VAF 7/10 reads (70%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.962); catalogued as rs562289968, COSV99349649; called by muse, mutect2, varscan2
- BRD3 | c.1756C>T p.R586W | Missense Mutation (SNP) | VAF 10/23 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV57704065; called by muse, mutect2, varscan2
- BTBD10 | c.996A>C p.E332D | Missense Mutation (SNP) | VAF 122/849 reads (14%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.897); catalogued as COSV99533545; called by muse, mutect2, varscan2
- BTRC | c.1780del p.R594Vfs*14 (on ENST00000370187 / NM_033637.4; = p.R558Vfs*14 on NM_003939.5) | Frame Shift Del (DEL) | VAF 114/477 reads (24%) | catalogued as rs774921343; called by mutect2, pindel, varscan2
- C3orf38 | c.519G>A p.W173* | Nonsense Mutation (SNP) | VAF 17/71 reads (24%) | catalogued as COSV59627722; called by muse, mutect2, varscan2
- CACNA1B | c.3217G>T p.D1073Y | Missense Mutation (SNP) | VAF 23/94 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.396); catalogued as rs1441288898, COSV99497004; called by muse, mutect2, varscan2
- CACNA1G | c.430A>G p.K144E | Missense Mutation (SNP) | VAF 22/178 reads (12%) | SIFT tolerated (0.18); PolyPhen benign (0.374); catalogued as COSV61729592; called by muse, mutect2, varscan2
- CACNA1I | c.3436G>A p.E1146K | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100360057; called by muse, varscan2
- CADM1 | c.187A>C p.S63R | Missense Mutation (SNP) | VAF 68/251 reads (27%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.771); catalogued as COSV100522576; called by muse, mutect2, varscan2
- CADPS | c.3217G>A p.A1073T | Missense Mutation (SNP) | VAF 75/233 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as rs147087123; called by muse, mutect2, varscan2
- CAMTA2 | c.1930C>T p.R644* | Nonsense Mutation (SNP) | VAF 16/56 reads (29%) | catalogued as rs147496832; called by muse, mutect2, varscan2
- CASP5 | c.533del p.N178Ifs*8 | Frame Shift Del (DEL) | VAF 64/200 reads (32%) | catalogued as rs765105588; called by mutect2, varscan2
- CASQ2 | c.669G>T p.E223D | Missense Mutation (SNP) | VAF 148/582 reads (25%) | SIFT tolerated (0.26); PolyPhen benign (0.013); catalogued as COSV99797408; called by muse, mutect2, varscan2
- CAVIN2 | c.1168G>A p.A390T | Missense Mutation (SNP) | VAF 26/116 reads (22%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.124); catalogued as COSV100414152; called by muse, mutect2, varscan2
- CCDC106 | c.725G>A p.R242H | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.95); catalogued as COSV58272641; called by muse, mutect2, varscan2
- CCDC112 | c.646G>A p.A216T | Missense Mutation (SNP) | VAF 62/270 reads (23%) | SIFT tolerated (0.39); PolyPhen benign (0.003); catalogued as COSV101100431; called by muse, mutect2, varscan2
- CCDC115 | c.86C>T p.T29M | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT tolerated (0.08); PolyPhen benign (0.07); catalogued as COSV99383704; called by muse, mutect2, varscan2
- CCDC14 | c.1775T>G p.V592G (on ENST00000488653; = p.V544G on NM_022757.5) | Missense Mutation (SNP) | VAF 92/355 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100113149; called by muse, mutect2, varscan2
- CCDC15 | c.581del p.K194Rfs*29 | Frame Shift Del (DEL) | VAF 30/92 reads (33%) | catalogued as rs759789184, COSV99049086; called by mutect2, varscan2
- CCDC28A | c.80del p.N27Mfs*5 | Frame Shift Del (DEL) | VAF 17/80 reads (21%) | catalogued as rs756347761; called by mutect2, varscan2
- CCDC30 | c.442del p.T148Lfs*6 (on ENST00000340612; = p.T105Lfs*6 on NM_001080850.3) | Frame Shift Del (DEL) | VAF 35/199 reads (18%) | catalogued as rs775731046; called by mutect2, pindel, varscan2
- CCDC34 | c.731del p.N244Mfs*28 | Frame Shift Del (DEL) | VAF 104/326 reads (32%) | catalogued as rs773019149; called by mutect2, varscan2
- CCDC63 | c.1616G>A p.R539Q | Missense Mutation (SNP) | VAF 84/204 reads (41%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.056); catalogued as rs776401462, COSV99960737; called by muse, mutect2, varscan2
- CCDC80 | c.794C>A p.P265H | Missense Mutation (SNP) | VAF 42/157 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV99244707; called by muse, mutect2, varscan2
- CCDC81 | c.1000C>G p.Q334E (on ENST00000445632 / NM_001156474.2; = p.Q244E on NM_021827.4) | Missense Mutation (SNP) | VAF 133/434 reads (31%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.937); catalogued as COSV99564265; called by muse, mutect2, varscan2
- CCDC88C | c.4993C>T p.P1665S | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100484845; called by muse, mutect2, varscan2
- CCDC9B | c.294del p.M99Wfs*3 | Frame Shift Del (DEL) | VAF 7/22 reads (32%) | catalogued as rs765438623; called by mutect2, pindel, varscan2
- CCN4 | c.349C>T p.Q117* | Nonsense Mutation (SNP) | VAF 12/61 reads (20%) | catalogued as rs980801009, COSV99137052; called by muse, mutect2, varscan2
- CCNA1 | c.731G>A p.R244H | Missense Mutation (SNP) | VAF 27/91 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs765233671, COSV55220035; called by muse, mutect2, varscan2
- CCNC | c.458A>G p.Y153C | Missense Mutation (SNP) | VAF 105/376 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV100412587; called by muse, mutect2, varscan2
- CCT8L2 | c.937G>A p.V313M | Missense Mutation (SNP) | VAF 14/49 reads (29%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs747115852, COSV100743275, COSV63462569; called by muse, mutect2, varscan2
- CD244 | c.853C>A p.Q285K (on ENST00000368033 / NM_001166663.2; = p.Q280K on NM_016382.4) | Missense Mutation (SNP) | VAF 22/517 reads (4%) | SIFT deleterious (0.04); PolyPhen benign (0.115); catalogued as COSV100458473; called by muse, mutect2
- CD70 | c.388G>A p.V130M | Missense Mutation (SNP) | VAF 16/63 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.821); catalogued as rs548095306, COSV55565708; called by muse, mutect2, varscan2
- CD72 | c.849C>A p.F283L | Missense Mutation (SNP) | VAF 51/135 reads (38%) | SIFT tolerated (0.67); PolyPhen benign (0); catalogued as COSV99427407; called by muse, mutect2, varscan2
- CDC20 | c.959A>T p.D320V | Missense Mutation (SNP) | VAF 13/34 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100196438; called by muse, mutect2, varscan2
- CDH16 | c.1586T>C p.V529A | Missense Mutation (SNP) | VAF 7/17 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100233553, COSV100233842; called by muse, varscan2
- CDH16 | c.940G>A p.E314K | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT tolerated (0.66); PolyPhen benign (0.403); catalogued as rs558954232, COSV100233686, COSV100233976; called by muse, mutect2, varscan2
- CDH9 | c.141G>T p.M47I | Missense Mutation (SNP) | VAF 289/1052 reads (27%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as COSV50279664, COSV99144018; called by muse, mutect2, varscan2
- CDK3 | c.217G>A p.E73K | Missense Mutation (SNP) | VAF 30/106 reads (28%) | SIFT deleterious (0.04); PolyPhen benign (0.129); catalogued as rs140567861, COSV56909913; called by muse, mutect2, varscan2
- CDK8 | c.515C>A p.A172D | Missense Mutation (SNP) | VAF 88/328 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as COSV101037164; called by muse, varscan2
- CDON | c.193G>A p.G65R | Missense Mutation (SNP) | VAF 69/186 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1012612060, COSV99701222; called by muse, mutect2, varscan2
- CEBPE | c.695C>T p.T232M | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs923787623, COSV52829648; called by muse, mutect2, varscan2
- CENPF | c.5477T>C p.I1826T | Missense Mutation (SNP) | VAF 13/67 reads (19%) | SIFT tolerated (0.4); PolyPhen benign (0.013); catalogued as COSV100871665; called by muse, mutect2, varscan2
- CENPK | c.65A>G p.E22G | Missense Mutation (SNP) | VAF 210/1130 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.341); catalogued as COSV99669441; called by muse, mutect2, varscan2
- CEP41 | c.584A>G p.Y195C | Missense Mutation (SNP) | VAF 71/492 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1554417028, COSV99782692; called by muse, mutect2, varscan2
- CEP43 | c.1083_1085del p.E361del | In Frame Del (DEL) | VAF 66/284 reads (23%) | catalogued as rs754383350; called by pindel, varscan2
- CERS5 | c.547C>A p.L183I | Missense Mutation (SNP) | VAF 83/464 reads (18%) | SIFT deleterious (0.05); PolyPhen benign (0.192); catalogued as COSV100451977; called by muse, mutect2, varscan2
- CFAP70 | c.2506C>T p.Q836* | Nonsense Mutation (SNP) | VAF 308/1086 reads (28%) | catalogued as COSV100160531; called by muse, varscan2
- CFAP74 | c.860C>T p.A287V | Missense Mutation (SNP) | VAF 12/24 reads (50%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.852); catalogued as rs768950775, COSV54564219; called by muse, mutect2
- CGA | c.229G>A p.V77I | Missense Mutation (SNP) | VAF 130/566 reads (23%) | SIFT tolerated (1); PolyPhen benign (0.022); catalogued as rs145503313; called by muse, mutect2, varscan2
- CHD3 | c.3738G>T p.K1246N | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.598); catalogued as COSV100391151; called by muse, mutect2, varscan2
- CHD6 | c.198G>T p.E66D | Missense Mutation (SNP) | VAF 129/315 reads (41%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.253); catalogued as COSV58559537; called by muse, mutect2, varscan2
- CHIT1 | c.448G>A p.V150I | Missense Mutation (SNP) | VAF 79/228 reads (35%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as rs557542364, COSV99705250; called by muse, mutect2, varscan2
- CHORDC1 | c.493-2A>T p.X165_splice | Splice Site (SNP) | VAF 78/236 reads (33%) | catalogued as COSV100272011; called by mutect2, varscan2
- CHRDL2 | c.889G>A p.E297K | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT tolerated (0.09); PolyPhen benign (0.026); catalogued as rs766415152, COSV99733726; called by muse, mutect2, varscan2
- CIT | c.416T>G p.V139G | Missense Mutation (SNP) | VAF 267/1052 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.53); catalogued as COSV99949402; called by muse, mutect2, varscan2
- CKMT2 | c.133C>T p.P45S | Missense Mutation (SNP) | VAF 22/83 reads (27%) | SIFT tolerated (0.78); PolyPhen benign (0.012); catalogued as COSV99562347; called by muse, mutect2, varscan2
- CLASP1 | c.2900G>T p.R967M | Missense Mutation (SNP) | VAF 150/546 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as COSV99754506; called by muse, mutect2, varscan2
- CLTC | c.1864C>A p.L622I | Missense Mutation (SNP) | VAF 32/150 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99292144; called by muse, mutect2, varscan2
- CNKSR1 | c.879G>A p.T293= (on ENST00000374253 / NM_001297647.2; = p.T286= on NM_006314.3) | Splice Region (SNP) | VAF 17/71 reads (24%) | catalogued as rs746626702, COSV64163261, COSV64163887; called by muse, mutect2, varscan2
- CNTN4 | c.2258C>T p.A753V | Missense Mutation (SNP) | VAF 16/462 reads (3%) | SIFT tolerated (0.08); PolyPhen benign (0.206); catalogued as COSV100639195; called by muse, mutect2
- CNTN5 | c.410G>T p.R137L | Missense Mutation (SNP) | VAF 121/414 reads (29%) | SIFT tolerated (1); PolyPhen benign (0.014); catalogued as COSV54303038, COSV99676123; called by muse, mutect2, varscan2
- CNTN5 | c.1222C>T p.R408* | Nonsense Mutation (SNP) | VAF 45/262 reads (17%) | catalogued as rs771353785, COSV99676130; called by muse, mutect2, varscan2
- CNTNAP2 | c.3047G>A p.R1016Q | Missense Mutation (SNP) | VAF 14/74 reads (19%) | SIFT tolerated (0.18); PolyPhen benign (0.074); catalogued as rs143879959, COSV62265209; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- COBL | c.2152C>T p.R718* | Nonsense Mutation (SNP) | VAF 16/32 reads (50%) | catalogued as rs372919855; called by muse, mutect2, varscan2
- COG2 | c.380del p.K127Rfs*5 | Frame Shift Del (DEL) | VAF 24/92 reads (26%) | catalogued as rs1188081815, COSV100794718; called by mutect2, varscan2
- COL12A1 | c.1742G>A p.R581H | Missense Mutation (SNP) | VAF 51/235 reads (22%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.999); catalogued as rs756803766, COSV59401555; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- COL21A1 | c.1058G>A p.R353H | Missense Mutation (SNP) | VAF 108/457 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.791); catalogued as rs1040526013, COSV55152168; called by muse, mutect2, varscan2
- COL22A1 | c.2161G>A p.V721I | Missense Mutation (SNP) | VAF 19/106 reads (18%) | SIFT tolerated (0.3); PolyPhen benign (0.001); catalogued as COSV100278154; called by muse, mutect2, varscan2
- COL25A1 | c.190G>A p.A64T | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT tolerated (0.34); PolyPhen benign (0.017); catalogued as rs1030036795, COSV101211381; called by muse, mutect2, varscan2
- COL6A3 | c.5440G>T p.E1814* | Nonsense Mutation (SNP) | VAF 11/39 reads (28%) | catalogued as COSV55080065, COSV99797868; called by muse, mutect2, varscan2
- COL6A3 | c.1574C>T p.T525M | Missense Mutation (SNP) | VAF 30/87 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.926); catalogued as rs755178814, COSV55080308; ClinVar: benign; called by muse, mutect2, varscan2
- COLGALT1 | c.500C>T p.A167V | Missense Mutation (SNP) | VAF 11/137 reads (8%) | SIFT tolerated (0.22); PolyPhen benign (0.023); catalogued as rs149722085; called by muse, mutect2
- COP1 | c.1121C>T p.T374I | Missense Mutation (SNP) | VAF 92/361 reads (25%) | SIFT tolerated (0.21); PolyPhen benign (0.278); catalogued as COSV100443179; called by muse, mutect2, varscan2
- CPA1 | c.643A>G p.I215V | Missense Mutation (SNP) | VAF 25/118 reads (21%) | SIFT tolerated (0.09); PolyPhen benign (0.082); catalogued as COSV99163259; called by muse, mutect2, varscan2
- CPEB2 | c.2962C>T p.Q988* | Nonsense Mutation (SNP) | VAF 405/1722 reads (24%) | catalogued as COSV99470254; called by muse, mutect2, varscan2
- CREB3 | c.282_285del p.S94Rfs*10 | Frame Shift Del (DEL) | VAF 19/72 reads (26%) | catalogued as rs1369727531; called by mutect2, pindel, varscan2
- CSE1L | c.2528C>T p.A843V | Missense Mutation (SNP) | VAF 167/486 reads (34%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.69); catalogued as rs749686049, COSV99521996; called by muse, mutect2, varscan2
- CSMD1 | c.4545C>A p.N1515K (on ENST00000520002; = p.N1514K on NM_033225.6) | Missense Mutation (SNP) | VAF 106/413 reads (26%) | SIFT tolerated (0.85); PolyPhen probably damaging (0.996); catalogued as COSV59359386; called by muse, mutect2, varscan2
- CSNK1E | c.379C>T p.R127W | Missense Mutation (SNP) | VAF 18/63 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV63292132; called by mutect2, varscan2
- CSNK2A2 | c.230del p.K77Rfs*3 | Frame Shift Del (DEL) | VAF 114/499 reads (23%) | catalogued as COSV52643307; called by mutect2, pindel, varscan2
- CTCF | c.1480C>T p.R494C | Missense Mutation (SNP) | VAF 37/129 reads (29%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.623); catalogued as COSV50490739; called by muse, mutect2, varscan2
- CTNNA1 | c.1055T>C p.M352T | Missense Mutation (SNP) | VAF 15/62 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.123); catalogued as COSV100242608; called by muse, mutect2, varscan2
- CXCR1 | c.226G>A p.V76I | Missense Mutation (SNP) | VAF 40/134 reads (30%) | SIFT tolerated (0.51); PolyPhen benign (0.019); catalogued as rs772327936, COSV99826320; called by muse, mutect2, varscan2
- CYB5R2 | c.589C>T p.L197F | Missense Mutation (SNP) | VAF 98/456 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV100207434; called by muse, mutect2, varscan2
- CYP2A6 | c.458C>T p.A153V | Missense Mutation (SNP) | VAF 15/79 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.161); catalogued as COSV56533848; called by muse, mutect2, varscan2
- CYP3A7 | c.56T>C p.L19P | Missense Mutation (SNP) | VAF 173/561 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100312637; called by muse, mutect2, varscan2
- CYP4F3 | c.827G>A p.R276H | Missense Mutation (SNP) | VAF 36/92 reads (39%) | SIFT tolerated (0.2); PolyPhen benign (0.024); catalogued as rs113330239, COSV55413386; called by muse, mutect2, varscan2
- CYP7B1 | c.982T>C p.S328P | Missense Mutation (SNP) | VAF 39/220 reads (18%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.979); catalogued as COSV100041570; called by muse, mutect2, varscan2
- DAAM2 | c.2900C>T p.A967V (on ENST00000274867 / NM_001201427.2; = p.A966V on NM_015345.3) | Missense Mutation (SNP) | VAF 12/31 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.757); catalogued as COSV99225511; called by muse, mutect2, varscan2
- DBH | c.590T>C p.L197P | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV99708026; called by muse, mutect2, varscan2
- DBP | c.829C>T p.R277W | Missense Mutation (SNP) | VAF 4/13 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99709321; called by muse, mutect2
- DCAF4L2 | c.1013C>T p.T338M | Missense Mutation (SNP) | VAF 28/102 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.777); catalogued as COSV60477323; called by muse, mutect2, varscan2
- DCPS | c.658G>A p.A220T | Missense Mutation (SNP) | VAF 20/90 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs554435261, COSV99703433; called by muse, mutect2, varscan2
- DDI1 | c.773T>C p.F258S | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100158971; called by muse, mutect2, varscan2
- DDIAS | c.393G>A p.T131= | Splice Region (SNP) | VAF 62/281 reads (22%) | catalogued as rs762266588, COSV61273188; called by muse, mutect2, varscan2
- DDR1 | c.2618C>T p.P873L (on ENST00000324771; = p.P836L on NM_001954.4) | Missense Mutation (SNP) | VAF 13/29 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs779035359, COSV100241448; called by muse, mutect2, varscan2
- DDX27 | c.2072del p.K691Rfs*4 | Frame Shift Del (DEL) | VAF 8/41 reads (20%) | catalogued as rs766714372; called by mutect2, varscan2
- DDX60L | c.3503del p.N1168Tfs*25 | Frame Shift Del (DEL) | VAF 102/363 reads (28%) | catalogued as rs772416332; called by mutect2, varscan2
- DENND2B | c.320C>T p.S107L | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0); catalogued as rs1258045916, COSV58203528; called by muse, mutect2
- DENND2C | c.1630G>C p.D544H (on ENST00000393274 / NM_001256404.2; = p.D487H on NM_198459.4) | Missense Mutation (SNP) | VAF 158/659 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101283921; called by muse, mutect2, varscan2
- DGCR8 | c.1007G>A p.G336E | Missense Mutation (SNP) | VAF 16/72 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.786); catalogued as COSV100707920; called by muse, mutect2, varscan2
- DHTKD1 | c.170C>T p.A57V | Missense Mutation (SNP) | VAF 99/431 reads (23%) | SIFT tolerated (0.5); PolyPhen benign (0.01); catalogued as rs749788470, COSV99536341; called by muse, mutect2, varscan2
- DIPK2B | c.38G>A p.R13H | Missense Mutation (SNP) | VAF 7/15 reads (47%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0); catalogued as rs759687156, COSV65005170; called by muse, varscan2
- DIS3L2 | c.2059C>T p.R687W | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT tolerated (0.08); PolyPhen benign (0.059); catalogued as rs372762400; ClinVar: uncertain significance; called by muse, varscan2
- DLG2 | c.698C>T p.A233V | Missense Mutation (SNP) | VAF 28/996 reads (3%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.972); catalogued as COSV99715317; called by muse, mutect2
- DLG5 | c.5465C>T p.P1822L | Missense Mutation (SNP) | VAF 29/116 reads (25%) | SIFT tolerated (1); PolyPhen possibly damaging (0.705); catalogued as rs931692281, COSV100967436; called by muse, mutect2, varscan2
- DMRTC2 | c.656T>C p.L219P | Missense Mutation (SNP) | VAF 12/47 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV99523377; called by muse, mutect2, varscan2
- DNA2 | c.2335del p.S779Hfs*6 | Frame Shift Del (DEL) | VAF 36/70 reads (51%) | catalogued as rs745893364; called by mutect2, varscan2
- DNAH11 | c.13240dup p.T4414Nfs*34 | Frame Shift Ins (INS) | VAF 16/60 reads (27%) | catalogued as rs759332741; called by mutect2, varscan2
- DNAH17 | c.5082G>T p.Q1694H | Missense Mutation (SNP) | VAF 26/105 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67761759; called by muse, mutect2, varscan2
- DNAH2 | c.5109G>T p.K1703N | Missense Mutation (SNP) | VAF 82/319 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV66722678; called by muse, mutect2, varscan2
- DNAH2 | c.7613G>A p.R2538Q | Missense Mutation (SNP) | VAF 63/221 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs772981855, COSV101209245, COSV101209286; called by muse, mutect2, varscan2
- DNAH2 | c.9929A>G p.D3310G | Missense Mutation (SNP) | VAF 52/326 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV101209248; called by muse, mutect2, varscan2
- DNAH3 | c.470C>A p.P157H | Missense Mutation (SNP) | VAF 111/514 reads (22%) | SIFT tolerated (0.09); PolyPhen benign (0.101); catalogued as COSV99767006; called by muse, mutect2, varscan2
- DNAH5 | c.11267G>T p.R3756M | Missense Mutation (SNP) | VAF 409/1634 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.489); catalogued as COSV99449037; called by muse, varscan2
- DNAH5 | c.9947del p.P3316Lfs*22 | Frame Shift Del (DEL) | VAF 22/70 reads (31%) | catalogued as rs1206989225; called by mutect2, pindel, varscan2
- DNAJC22 | c.224del p.P75Lfs*2 | Frame Shift Del (DEL) | VAF 6/21 reads (29%) | catalogued as rs751047585; called by mutect2, varscan2
- DNMT1 | c.3866G>A p.R1289H | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs564106859, COSV100532381; called by muse, varscan2
- DOCK2 | c.626A>G p.Y209C | Missense Mutation (SNP) | VAF 158/706 reads (22%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.662); catalogued as COSV99911966; called by muse, mutect2, varscan2
- DOCK3 | c.5555del p.P1852Qfs*45 | Frame Shift Del (DEL) | VAF 20/56 reads (36%) | catalogued as rs782552436; called by mutect2, pindel, varscan2
- DOCK9 | c.248C>T p.A83V (on ENST00000376460 / NM_001366676.2; = p.A84V on NM_015296.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 101/369 reads (27%) | SIFT tolerated (0.39); PolyPhen benign (0.205); catalogued as COSV100239040; called by muse, mutect2, varscan2
- DPYD | c.1181G>A p.R394Q | Missense Mutation (SNP) | VAF 127/460 reads (28%) | SIFT tolerated (0.27); PolyPhen benign (0.156); catalogued as rs143815742, COSV64604165; called by muse, mutect2, varscan2
- DSCAML1 | c.739G>A p.V247I (on ENST00000321322; = p.V187I on NM_020693.4) | Missense Mutation (SNP) | VAF 44/109 reads (40%) | SIFT tolerated (0.07); PolyPhen benign (0.397); catalogued as rs754760476, COSV100355757; called by muse, mutect2, varscan2
- DSPP | c.986C>A p.S329Y | Missense Mutation (SNP) | VAF 14/49 reads (29%) | SIFT tolerated, low confidence (0.9); PolyPhen possibly damaging (0.516); catalogued as rs376443462; called by muse, mutect2, varscan2
- DYNC1I2 | c.169del p.R57Gfs*13 | Frame Shift Del (DEL) | VAF 37/110 reads (34%) | catalogued as rs772082432; called by mutect2, varscan2
- DYNC2H1 | c.5176C>T p.R1726* | Nonsense Mutation (SNP) | VAF 533/1827 reads (29%) | catalogued as rs772321133, CM130524, COSV100518383; called by muse, mutect2, varscan2
- DYNC2H1 | c.10114A>T p.T3372S | Missense Mutation (SNP) | VAF 37/151 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as COSV100518384; called by muse, mutect2, varscan2
- DYNC2I1 | c.2743A>G p.I915V | Missense Mutation (SNP) | VAF 10/241 reads (4%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.487); catalogued as COSV101337661; called by muse, mutect2
- ECM2 | c.30dup p.L11Sfs*8 | Frame Shift Ins (INS) | VAF 86/301 reads (29%) | catalogued as rs752987091; called by mutect2, varscan2
- EHBP1 | c.2630G>A p.R877Q | Missense Mutation (SNP) | VAF 58/206 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.99); catalogued as rs201434475, COSV99860750; called by muse, mutect2, varscan2
- EIF2AK1 | c.367G>C p.A123P | Missense Mutation (SNP) | VAF 20/74 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV52241731, COSV99551837; called by muse, varscan2
- EIF2B1 | c.439C>T p.R147* | Nonsense Mutation (SNP) | VAF 28/174 reads (16%) | catalogued as rs370678173; called by muse, mutect2, varscan2
- EIF2B2 | c.127C>T p.R43C | Missense Mutation (SNP) | VAF 2/8 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as rs372838502; called by muse, mutect2
- EIF3F | c.941A>G p.Q314R | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT tolerated (0.47); PolyPhen benign (0.186); catalogued as rs765505343, COSV100562551; called by muse, mutect2, varscan2
- EIF3H | c.550C>A p.P184T | Missense Mutation (SNP) | VAF 32/518 reads (6%) | SIFT tolerated (0.22); PolyPhen benign (0.039); catalogued as rs776462055; called by muse, mutect2
- EIF3K | c.626-1G>T p.X209_splice | Splice Site (SNP) | VAF 18/335 reads (5%) | catalogued as COSV99943011; called by muse, mutect2
- ELAVL2 | c.526C>T p.R176* | Nonsense Mutation (SNP) | VAF 160/578 reads (28%) | catalogued as COSV56365323; called by muse, mutect2, varscan2
- ELF1 | c.1472C>T p.A491V | Missense Mutation (SNP) | VAF 63/240 reads (26%) | SIFT tolerated (0.34); PolyPhen benign (0.011); catalogued as rs766946264, COSV99523011; called by muse, mutect2, varscan2
- ELF1 | c.937C>T p.P313S | Missense Mutation (SNP) | VAF 37/139 reads (27%) | SIFT tolerated (0.56); PolyPhen benign (0.003); catalogued as COSV99523013; called by muse, mutect2, varscan2
- ELK3 | c.14T>C p.I5T | Missense Mutation (SNP) | VAF 18/59 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99957593; called by muse, mutect2, varscan2
- EME1 | c.1667A>G p.Q556R | Missense Mutation (SNP) | VAF 20/103 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.957); catalogued as COSV99869533; called by muse, mutect2, varscan2
- EPG5 | c.1805C>T p.P602L | Missense Mutation (SNP) | VAF 195/673 reads (29%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.723); catalogued as COSV99957123, COSV99958212; called by muse, mutect2, varscan2
- EPHA3 | c.476A>G p.D159G | Missense Mutation (SNP) | VAF 145/577 reads (25%) | SIFT tolerated (0.52); PolyPhen probably damaging (0.995); catalogued as COSV100344839; called by muse, mutect2, varscan2
- EPHA3 | c.2538del p.M847Wfs*10 | Frame Shift Del (DEL) | VAF 26/109 reads (24%) | catalogued as rs1317589623; called by mutect2, pindel, varscan2
- EPHA3 | c.2947G>A p.V983M | Missense Mutation (SNP) | VAF 39/107 reads (36%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.981); catalogued as rs536144760, COSV60694629, COSV60712421; called by muse, mutect2, varscan2
- EPHA5 | c.1057G>A p.A353T | Missense Mutation (SNP) | VAF 216/819 reads (26%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.459); catalogued as COSV56647879; called by muse, mutect2, varscan2
- EPX | c.751G>A p.V251I | Missense Mutation (SNP) | VAF 33/101 reads (33%) | SIFT tolerated (0.76); PolyPhen benign (0.015); catalogued as rs762203083, COSV99836468; called by muse, mutect2, varscan2
- ERBB4 | c.2867-1G>A p.X956_splice | Splice Site (SNP) | VAF 33/170 reads (19%) | catalogued as COSV100726439, COSV61493101; called by muse, mutect2, varscan2
- ERCC3 | c.1183G>A p.D395N | Missense Mutation (SNP) | VAF 36/104 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.418); catalogued as COSV53425816; called by muse, mutect2, varscan2
- ERICH5 | c.853C>T p.P285S | Missense Mutation (SNP) | VAF 79/337 reads (23%) | SIFT tolerated (0.68); PolyPhen benign (0); catalogued as rs1167461070, COSV100582758; called by muse, mutect2, varscan2
- ERICH6 | c.1151T>C p.V384A | Missense Mutation (SNP) | VAF 96/415 reads (23%) | SIFT tolerated (0.85); PolyPhen benign (0.007); catalogued as COSV99901607; called by muse, mutect2, varscan2
- ERLEC1 | c.494G>A p.R165Q | Missense Mutation (SNP) | VAF 102/394 reads (26%) | SIFT tolerated (0.61); PolyPhen benign (0.001); catalogued as rs748288717, COSV99483013, COSV99483134; called by muse, mutect2, varscan2
- EVC | c.568C>T p.R190C | Missense Mutation (SNP) | VAF 16/54 reads (30%) | SIFT tolerated (0.07); PolyPhen benign (0.067); catalogued as rs1286815295, COSV53832353; called by muse, mutect2, varscan2
- EXOC4 | c.209C>T p.T70M | Missense Mutation (SNP) | VAF 120/433 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1290075190, COSV99553590; called by muse, mutect2, varscan2
- F2 | c.1474T>G p.L492V | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100319483; called by muse, mutect2, varscan2
- FADD | c.485T>C p.V162A | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as COSV100096645; called by muse, mutect2, varscan2
- FAIM2 | c.839G>A p.R280Q | Missense Mutation (SNP) | VAF 32/100 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.593); catalogued as rs751246525, COSV57738910; called by muse, mutect2, varscan2
- FAM120AOS | c.640G>A p.A214T | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.001); catalogued as COSV99465253; called by muse, mutect2, varscan2
- FAM120B | c.2237C>T p.A746V | Missense Mutation (SNP) | VAF 103/488 reads (21%) | SIFT tolerated (0.28); PolyPhen benign (0.159); catalogued as COSV99379288; called by muse, mutect2, varscan2
- FAM221B | c.610C>T p.R204C | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.809); catalogued as rs943024291, COSV65074389; called by muse, mutect2, varscan2
- FANCD2 | c.3860G>T p.S1287I | Missense Mutation (SNP) | VAF 85/355 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as COSV99810345, COSV99811141; called by muse, mutect2, varscan2
- FANCE | c.929dup p.V311Sfs*2 | Frame Shift Ins (INS) | VAF 12/50 reads (24%) | catalogued as rs587778337; ClinVar: not provided; called by mutect2, varscan2
- FANCM | c.1171G>A p.D391N | Missense Mutation (SNP) | VAF 67/203 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.118); catalogued as COSV99950980; called by muse, mutect2, varscan2
- FAT2 | c.5448T>A p.D1816E | Missense Mutation (SNP) | VAF 15/34 reads (44%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV55812391; called by muse, mutect2, varscan2
- FAT2 | c.2869G>A p.A957T | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.772); catalogued as rs538842194, COSV55826643; called by muse, varscan2
- FAT4 | c.8624G>A p.S2875N | Missense Mutation (SNP) | VAF 36/112 reads (32%) | SIFT tolerated (0.07); PolyPhen benign (0.06); catalogued as rs765905172, COSV100628413; called by muse, mutect2, varscan2
- FBN2 | c.6412del p.D2138Tfs*111 | Frame Shift Del (DEL) | VAF 100/403 reads (25%) | catalogued as COSV52520596; called by mutect2, pindel, varscan2
- FBXO11 | c.2359G>A p.A787T (on ENST00000403359 / NM_001190274.2; = p.A703T on NM_025133.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 98/436 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as COSV99315823; called by muse, mutect2, varscan2
- FBXO11 | c.1295C>T p.A432V (on ENST00000403359 / NM_001190274.2; = p.A348V on NM_025133.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 43/261 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.953); catalogued as COSV57016534; called by muse, mutect2, varscan2
- FBXW10 | c.2854C>T p.R952C | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as rs1290401881, COSV100111396; called by muse, mutect2
- FCHSD1 | c.1543G>A p.E515K | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.069); catalogued as rs768710494, COSV51836784; called by muse, mutect2
- FCRL5 | c.380C>A p.A127E | Missense Mutation (SNP) | VAF 26/127 reads (20%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.449); catalogued as COSV100708750, COSV62519780; called by muse, mutect2, varscan2
- FGFBP1 | c.353G>A p.R118Q | Missense Mutation (SNP) | VAF 114/464 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.742); catalogued as rs199528852, COSV52586067; called by muse, mutect2, varscan2
- FKBP15 | c.3307G>A p.E1103K | Missense Mutation (SNP) | VAF 85/311 reads (27%) | SIFT tolerated, low confidence (0.66); PolyPhen benign (0); catalogued as rs572313532, COSV53031810; called by muse, mutect2, varscan2
- FLCN | c.1390G>A p.E464K | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT tolerated (0.16); PolyPhen benign (0.015); catalogued as rs1471793185, COSV53263731, COSV99550214; called by muse, mutect2, varscan2
- FLG | c.5912C>A p.A1971E | Missense Mutation (SNP) | VAF 27/70 reads (39%) | SIFT tolerated (0.09); PolyPhen benign (0.021); catalogued as COSV100911509; called by muse, mutect2, varscan2
- FLG | c.4549T>C p.Y1517H | Missense Mutation (SNP) | VAF 27/111 reads (24%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as COSV100911510; called by muse, mutect2, varscan2
- FLG | c.3412A>G p.T1138A | Missense Mutation (SNP) | VAF 35/167 reads (21%) | SIFT tolerated (0.18); PolyPhen benign (0.048); catalogued as rs750063141, COSV100911511; called by muse, mutect2, varscan2
- FLII | c.3609G>T p.E1203D | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT tolerated (0.17); PolyPhen benign (0.243); catalogued as COSV100375319; called by muse, mutect2
- FLRT2 | c.664G>A p.A222T | Missense Mutation (SNP) | VAF 15/66 reads (23%) | SIFT tolerated (0.06); PolyPhen benign (0.015); catalogued as rs140606612; called by muse, mutect2, varscan2
- FNBP1L | c.1168C>A p.P390T (on ENST00000271234 / NM_001164473.2; = p.P332T on NM_017737.5) | Missense Mutation (SNP) | VAF 27/90 reads (30%) | SIFT tolerated (0.18); PolyPhen benign (0.005); catalogued as COSV99554346; called by muse, mutect2, varscan2
- FREM1 | c.2515del p.S839Lfs*8 | Frame Shift Del (DEL) | VAF 206/537 reads (38%) | catalogued as COSV66527755; called by mutect2, pindel, varscan2
- FRMD3 | c.1303dup p.I435Nfs*10 | Frame Shift Ins (INS) | VAF 75/376 reads (20%) | catalogued as rs1353070115; called by mutect2, pindel, varscan2
- FSD2 | c.1646del p.G549Afs*4 | Frame Shift Del (DEL) | VAF 15/78 reads (19%) | catalogued as rs1246402267; called by mutect2, pindel, varscan2
- FSD2 | c.235G>A p.G79R | Missense Mutation (SNP) | VAF 105/353 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.893); catalogued as COSV100575115; called by muse, mutect2, varscan2
- GABPB1 | c.386A>G p.D129G | Missense Mutation (SNP) | VAF 26/808 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV99589768; called by muse, mutect2
- GABPB1 | c.220C>T p.P74S | Missense Mutation (SNP) | VAF 122/361 reads (34%) | SIFT deleterious (0.02); PolyPhen benign (0.125); catalogued as COSV55014557; called by muse, varscan2
- GABRQ | c.1088G>T p.R363M | Missense Mutation (SNP) | VAF 110/289 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV100941217, COSV64782025; called by muse, mutect2, varscan2
- GALNT14 | c.1165T>A p.L389M | Missense Mutation (SNP) | VAF 14/220 reads (6%) | SIFT tolerated (0.12); PolyPhen benign (0.161); catalogued as COSV100204546; called by muse, mutect2
- GALNT6 | c.1111A>G p.T371A | Missense Mutation (SNP) | VAF 27/147 reads (18%) | SIFT tolerated (0.09); PolyPhen benign (0.254); catalogued as COSV100695426; called by muse, mutect2, varscan2
- GAREM1 | c.1798C>T p.R600* (on ENST00000269209 / NM_001242409.2; = p.R599* on NM_022751.3) | Nonsense Mutation (SNP) | VAF 12/81 reads (15%) | catalogued as COSV52505678, COSV99331146; called by muse, mutect2
- GAS7 | c.1163A>G p.D388G (on ENST00000432992 / NM_201433.2; = p.D248G on NM_003644.3) | Missense Mutation (SNP) | VAF 50/182 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.946); catalogued as COSV100095348; called by muse, mutect2, varscan2
- GAS8 | c.472G>A p.V158M | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT tolerated (0.13); PolyPhen benign (0.03); catalogued as COSV99243943; called by muse, mutect2
- GBE1 | c.1360G>T p.D454Y | Missense Mutation (SNP) | VAF 222/829 reads (27%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.95); catalogued as COSV101450075; called by muse, mutect2, varscan2
- GBF1 | c.5114G>A p.R1705H (on ENST00000369983 / NM_001377137.1; = p.R1704H on NM_004193.3) | Missense Mutation (SNP) | VAF 13/54 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1482283229, COSV64144738; called by muse, mutect2, varscan2
- GCC1 | c.1310A>G p.E437G | Missense Mutation (SNP) | VAF 15/36 reads (42%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.761); catalogued as COSV100365510; called by muse, mutect2, varscan2
- GCNT3 | c.652G>C p.V218L | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.832); catalogued as COSV101251810; called by muse, mutect2
- GDAP2 | c.1231G>A p.D411N | Missense Mutation (SNP) | VAF 229/738 reads (31%) | SIFT tolerated (0.68); PolyPhen possibly damaging (0.837); catalogued as rs754920481, COSV65612689; called by muse, mutect2, varscan2
- GDPD3 | c.437C>A p.P146H | Missense Mutation (SNP) | VAF 18/52 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99531518; called by muse, mutect2, varscan2
- GGN | c.1066G>A p.A356T | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.001); catalogued as rs1474770509, COSV53057252; called by muse, varscan2
- GHSR | c.40C>T p.L14F | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT tolerated, low confidence (0.66); PolyPhen benign (0); catalogued as rs1004821824, COSV53839796; called by muse, mutect2, varscan2
- GMPPA | c.544G>A p.G182S | Missense Mutation (SNP) | VAF 72/246 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV100354621; called by muse, mutect2, varscan2
- GNB1 | c.946A>G p.S316G | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV66100072; called by muse, mutect2, varscan2
- GNPDA2 | c.282del p.F94Lfs*6 | Frame Shift Del (DEL) | VAF 46/158 reads (29%) | catalogued as rs1489322870; called by mutect2, varscan2
- GOLGA3 | c.4258G>A p.V1420M | Missense Mutation (SNP) | VAF 21/38 reads (55%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.985); catalogued as rs142000244; called by mutect2, varscan2
- GOLGB1 | c.2838del p.E947Sfs*20 | Frame Shift Del (DEL) | VAF 24/244 reads (10%) | catalogued as rs774978171; called by mutect2, pindel
- GON4L | c.791C>T p.A264V | Missense Mutation (SNP) | VAF 190/811 reads (23%) | SIFT tolerated (0.09); PolyPhen benign (0.001); catalogued as COSV99674133; called by muse, varscan2
- GPLD1 | c.2019C>T p.Y673= | Splice Region (SNP) | VAF 24/69 reads (35%) | catalogued as rs140430161; called by muse, mutect2, varscan2
- GPR143 | c.968C>A p.P323H | Missense Mutation (SNP) | VAF 23/75 reads (31%) | SIFT tolerated (0.07); PolyPhen benign (0.036); catalogued as COSV101102214; called by muse, mutect2, varscan2
- GPR151 | c.923T>C p.V308A | Missense Mutation (SNP) | VAF 25/132 reads (19%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as COSV99694736; called by muse, mutect2, varscan2
- GPR65 | c.371del p.F124Sfs*2 | Frame Shift Del (DEL) | VAF 48/199 reads (24%) | catalogued as rs770829884; called by mutect2, varscan2
- GPRIN1 | c.1760C>T p.S587L | Missense Mutation (SNP) | VAF 18/36 reads (50%) | SIFT tolerated (0.61); PolyPhen benign (0); catalogued as rs1193082156, COSV99991498; called by muse, mutect2, varscan2
- GPX5 | c.205G>A p.V69M | Missense Mutation (SNP) | VAF 47/229 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs376708612; called by muse, mutect2, varscan2
- GPX6 | c.602A>C p.Q201P | Missense Mutation (SNP) | VAF 64/222 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.001); catalogued as COSV100724827; called by muse, mutect2, varscan2
- GRAMD1B | c.1684C>T p.R562W | Missense Mutation (SNP) | VAF 68/213 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs772035485, COSV59200080; called by muse, mutect2, varscan2
- GRIK4 | c.17C>T p.A6V | Missense Mutation (SNP) | VAF 85/318 reads (27%) | SIFT tolerated (0.09); PolyPhen benign (0.019); catalogued as rs753839952, COSV101483608; called by muse, mutect2, varscan2
- GRIN2A | c.1273del p.L425* | Frame Shift Del (DEL) | VAF 56/264 reads (21%) | catalogued as rs879253760; ClinVar: uncertain significance; called by mutect2, pindel, varscan2
- H2BC12 | c.278G>A p.R93K | Missense Mutation (SNP) | VAF 22/92 reads (24%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.318); catalogued as COSV100804657; called by muse, mutect2, varscan2
- H3-5 | c.239C>T p.T80I | Missense Mutation (SNP) | VAF 37/106 reads (35%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.777); catalogued as rs1215758766, COSV100461642; called by muse, mutect2, varscan2
- HAPLN3 | c.355G>A p.V119M | Missense Mutation (SNP) | VAF 6/12 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs772799052, COSV62084253; called by muse, mutect2, varscan2
- HDAC6 | c.991G>A p.A331T | Missense Mutation (SNP) | VAF 69/208 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.265); catalogued as rs781914689, COSV100490770; called by muse, mutect2, varscan2
- HEATR5B | c.3731G>A p.R1244H | Missense Mutation (SNP) | VAF 36/178 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.792); catalogued as rs1450720418, COSV99249154; called by muse, mutect2, varscan2
- HECTD4 | c.10853A>G p.D3618G | Missense Mutation (SNP) | VAF 27/91 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.438); catalogued as COSV101107374; called by muse, mutect2, varscan2
- HELB | c.632C>A p.A211D | Missense Mutation (SNP) | VAF 30/1204 reads (2%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99921871; called by muse, mutect2
- HEPACAM2 | c.935A>G p.D312G (on ENST00000394468 / NM_001039372.4; = p.D300G on NM_198151.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 550/2053 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.119); catalogued as COSV100506524; called by muse, mutect2, varscan2
- HEPHL1 | c.967G>A p.V323I | Missense Mutation (SNP) | VAF 67/277 reads (24%) | SIFT tolerated (1); PolyPhen benign (0.042); catalogued as rs183813405, COSV59890169; called by muse, mutect2, varscan2
- HEXIM2 | c.142C>T p.R48W | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.335); catalogued as rs756765702, COSV100217906, COSV56236823; called by muse, mutect2
- HIGD1B | c.155G>A p.R52H | Missense Mutation (SNP) | VAF 47/158 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs150260178; called by muse, varscan2
- HIP1 | c.123T>C p.T41= | Splice Region (SNP) | VAF 82/275 reads (30%) | catalogued as COSV100417438; called by muse, mutect2, varscan2
- HIPK1 | c.2708T>C p.V903A | Missense Mutation (SNP) | VAF 44/196 reads (22%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.9); catalogued as COSV100478909; called by muse, mutect2, varscan2
- HIRIP3 | c.1237A>G p.K413E | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as COSV99662999; called by muse, mutect2, varscan2
- HMCN1 | c.16003G>A p.G5335S | Missense Mutation (SNP) | VAF 33/107 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs775664458, COSV99628397; called by muse, mutect2, varscan2
- HMG20A | c.744G>T p.E248D | Missense Mutation (SNP) | VAF 7/38 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.857); catalogued as COSV100287742; called by muse, mutect2
- HMMR | c.1998del p.K666Nfs*11 | Frame Shift Del (DEL) | VAF 44/151 reads (29%) | catalogued as rs761272507; called by mutect2, varscan2
- HRC | c.1744C>T p.P582S | Missense Mutation (SNP) | VAF 19/66 reads (29%) | SIFT tolerated (0.2); PolyPhen benign (0.143); catalogued as rs1391905788, COSV99417874; called by muse, mutect2, varscan2
- HSPA1L | c.613G>T p.G205C | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV100989375; called by muse, mutect2, varscan2
- IFT140 | c.1890A>C p.Q630H | Missense Mutation (SNP) | VAF 113/497 reads (23%) | SIFT tolerated (0.1); PolyPhen benign (0.006); catalogued as COSV101276374; called by muse, mutect2, varscan2
- IFT140 | c.1424G>A p.R475Q | Missense Mutation (SNP) | VAF 15/63 reads (24%) | SIFT tolerated (0.15); PolyPhen benign (0.037); catalogued as rs776789813, COSV68486659; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- IFT172 | c.4228G>A p.V1410M | Missense Mutation (SNP) | VAF 34/135 reads (25%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.751); catalogued as COSV53135936, COSV99562394; called by muse, mutect2, varscan2
- IGSF10 | c.2003G>A p.R668K | Missense Mutation (SNP) | VAF 300/1058 reads (28%) | SIFT tolerated (0.44); PolyPhen benign (0.001); catalogued as rs148479279; called by muse, mutect2, varscan2
- IGSF22 | c.1972C>T p.R658C | Missense Mutation (SNP) | VAF 17/48 reads (35%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.877); catalogued as rs747280828, COSV100079660; called by muse, mutect2, varscan2
- IL1A | c.505G>T p.G169C | Missense Mutation (SNP) | VAF 9/39 reads (23%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.958); catalogued as COSV99641360; called by muse, mutect2
- IL27RA | c.1819G>A p.A607T | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT tolerated (0.44); PolyPhen benign (0.001); catalogued as rs376141649, COSV54601751; called by muse, mutect2, varscan2
- INPP5F | c.919T>C p.Y307H | Missense Mutation (SNP) | VAF 19/75 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); catalogued as COSV100740106; called by muse, mutect2, varscan2
- IPCEF1 | c.243+2T>C p.X81_splice | Splice Site (SNP) | VAF 144/526 reads (27%) | catalogued as COSV99499599; called by muse, mutect2, varscan2
- IPO5 | c.1799A>C p.Q600P | Missense Mutation (SNP) | VAF 35/1058 reads (3%) | SIFT deleterious (0); PolyPhen possibly damaging (0.896); catalogued as COSV55154069, COSV99847210; called by muse, mutect2
- IRS1 | c.1370G>A p.R457H | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.981); catalogued as rs755583840, COSV100524433; called by muse, varscan2
- IRX2 | c.253G>A p.A85T | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.022); catalogued as COSV100121697; called by muse, mutect2, varscan2
- ITGA3 | c.2554C>G p.L852V | Missense Mutation (SNP) | VAF 9/58 reads (16%) | SIFT tolerated (1); PolyPhen benign (0.045); catalogued as COSV99143565; called by muse, mutect2, varscan2
- ITGAD | c.2616C>T p.N872= | Splice Region (SNP) | VAF 8/17 reads (47%) | catalogued as rs145843729; called by muse, mutect2
- ITPR1 | c.2088G>T p.E696D (on ENST00000354582; = p.E681D on NM_002222.7) | Missense Mutation (SNP) | VAF 111/403 reads (28%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.995); catalogued as COSV100230879; called by muse, mutect2, varscan2
- ITPR3 | c.6974G>A p.G2325D | Missense Mutation (SNP) | VAF 21/286 reads (7%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.555); catalogued as COSV100967290; called by muse, mutect2
- ITPR3 | c.7933G>A p.E2645K | Missense Mutation (SNP) | VAF 13/39 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs753797425, COSV100951994; called by muse, mutect2, varscan2
- IVL | c.128del p.P43Hfs*22 | Frame Shift Del (DEL) | VAF 11/47 reads (23%) | catalogued as COSV64216943; called by mutect2, pindel, varscan2
- KBTBD7 | c.1032G>T p.E344D | Missense Mutation (SNP) | VAF 17/58 reads (29%) | SIFT deleterious (0.05); PolyPhen benign (0.003); catalogued as COSV101068094; called by muse, mutect2, varscan2
- KCNA10 | c.724C>T p.R242W | Missense Mutation (SNP) | VAF 64/228 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.851); catalogued as rs776640538, COSV63904732; called by muse, mutect2, varscan2
- KCNH7 | c.968T>A p.L323H | Missense Mutation (SNP) | VAF 197/702 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV100035587; called by muse, mutect2, varscan2
- KCNIP1 | c.194A>G p.Q65R (on ENST00000411494 / NM_001034837.3; = p.Q54R on NM_014592.4) | Missense Mutation (SNP) | VAF 11/83 reads (13%) | SIFT tolerated (0.09); PolyPhen benign (0.007); catalogued as rs1008260063, COSV100199179; called by muse, mutect2, varscan2
- KCNJ11 | c.662G>A p.R221H | Missense Mutation (SNP) | VAF 5/11 reads (45%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.937); catalogued as rs768909861, COSV60595626, COSV60595643; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- KCNK1 | c.730C>T p.L244F | Missense Mutation (SNP) | VAF 50/173 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.826); catalogued as rs776795446, COSV100785688; called by muse, mutect2, varscan2
- KCNK13 | c.841A>G p.I281V | Missense Mutation (SNP) | VAF 83/344 reads (24%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.928); catalogued as rs114305114, COSV99965644; called by muse, mutect2, varscan2
- KCNQ3 | c.515C>T p.A172V | Missense Mutation (SNP) | VAF 13/48 reads (27%) | SIFT tolerated (0.15); PolyPhen benign (0.266); catalogued as COSV101196004; called by muse, mutect2, varscan2
- KCTD16 | c.697C>A p.L233M | Missense Mutation (SNP) | VAF 11/197 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV101568803; called by muse, mutect2
- KHNYN | c.1339G>A p.V447M | Missense Mutation (SNP) | VAF 6/12 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs750247971, COSV99249977; called by muse, varscan2
- KIAA1109 | c.11847A>G p.A3949= | Splice Region (SNP) | VAF 36/92 reads (39%) | catalogued as COSV99158746; called by muse, mutect2, varscan2
- KIAA1841 | c.214T>C p.S72P | Missense Mutation (SNP) | VAF 9/42 reads (21%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99693614; called by muse, mutect2, varscan2
- KIAA2026 | c.4549A>G p.T1517A | Missense Mutation (SNP) | VAF 150/570 reads (26%) | SIFT tolerated (0.2); PolyPhen benign (0.003); catalogued as rs747635824, COSV101198994; called by muse, varscan2
- KIF18B | c.2359G>A p.V787I (on ENST00000593135 / NM_001265577.2; = p.V799I on NM_001264573.2) | Missense Mutation (SNP) | VAF 9/38 reads (24%) | SIFT tolerated (0.44); PolyPhen benign (0.001); catalogued as rs745510143, COSV59274132; called by muse, mutect2, varscan2
- KIF21A | c.1036G>A p.A346T | Missense Mutation (SNP) | VAF 220/1026 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs143166999; called by muse, mutect2, varscan2
- KIF21B | c.352G>A p.A118T | Missense Mutation (SNP) | VAF 9/47 reads (19%) | SIFT tolerated (0.5); PolyPhen benign (0.003); catalogued as rs770974908, COSV59752730; called by muse, mutect2, varscan2
- KIRREL3 | c.1052A>G p.D351G | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV101585703; called by muse, mutect2, varscan2
- KLC4 | c.526G>T p.D176Y | Missense Mutation (SNP) | VAF 32/106 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99431838; called by muse, mutect2, varscan2
- KLF8 | c.1061G>A p.R354H | Missense Mutation (SNP) | VAF 41/86 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV63848092; called by muse, mutect2, varscan2
- KLHL41 | c.215del p.K72Rfs*3 | Frame Shift Del (DEL) | VAF 34/124 reads (27%) | catalogued as COSV52930337; called by mutect2, varscan2
- KLRC3 | c.637C>T p.R213C | Missense Mutation (SNP) | VAF 167/364 reads (46%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.72); catalogued as rs569300623, COSV101122906, COSV67250668; called by muse, mutect2, varscan2
- KMT2C | c.7387C>T p.R2463C | Missense Mutation (SNP) | VAF 115/239 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.791); catalogued as rs750213944, COSV100071198; called by muse, mutect2, varscan2
- KRI1 | c.1359C>T p.N453= | Splice Region (SNP) | VAF 12/26 reads (46%) | catalogued as rs780845086, COSV100470064; called by muse, mutect2, varscan2
- KRT3 | c.1874G>A p.R625H | Missense Mutation (SNP) | VAF 32/86 reads (37%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.033); catalogued as rs1315514569, COSV100527026; called by muse, mutect2, varscan2
- KRT6C | c.1663T>A p.S555T | Missense Mutation (SNP) | VAF 455/1093 reads (42%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99359944; called by muse, mutect2, varscan2
- KRT82 | c.1255A>G p.T419A | Missense Mutation (SNP) | VAF 15/38 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99233535; called by muse, mutect2, varscan2
- KRTAP10-6 | c.1034G>A p.C345Y | Missense Mutation (SNP) | VAF 14/69 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.133); catalogued as COSV100553247; called by muse, mutect2, varscan2
- KSR2 | c.1606del p.L536Sfs*61 | Frame Shift Del (DEL) | VAF 33/180 reads (18%) | catalogued as rs770565486; called by mutect2, pindel, varscan2
- LAIR1 | c.790G>A p.A264T | Missense Mutation (SNP) | VAF 30/92 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as COSV57308730; called by muse, mutect2, varscan2
- LAMA1 | c.1487del p.N496Tfs*27 | Frame Shift Del (DEL) | VAF 28/123 reads (23%) | catalogued as rs1406609727; called by mutect2, pindel, varscan2
- LANCL2 | c.551C>T p.S184L | Missense Mutation (SNP) | VAF 28/133 reads (21%) | SIFT tolerated (0.26); PolyPhen benign (0.007); catalogued as rs776099480, COSV54649306, COSV54651496; called by muse, mutect2, varscan2
- LARGE1 | c.544C>A p.L182M | Missense Mutation (SNP) | VAF 132/562 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100505200; called by muse, mutect2, varscan2
- LARP4B | c.2113G>T p.A705S | Missense Mutation (SNP) | VAF 15/86 reads (17%) | SIFT tolerated (0.1); PolyPhen benign (0.013); catalogued as COSV100295294; called by muse, mutect2, varscan2
- LIPE | c.2026G>A p.A676T | Missense Mutation (SNP) | VAF 12/56 reads (21%) | SIFT tolerated (0.09); PolyPhen benign (0.265); catalogued as rs1434397516, COSV99734068; called by muse, mutect2, varscan2
- LRCH4 | c.176G>C p.R59P | Missense Mutation (SNP) | VAF 14/40 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV99575276; called by muse, varscan2
- LRIG2 | c.3130A>G p.R1044G | Missense Mutation (SNP) | VAF 34/119 reads (29%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.054); catalogued as COSV100743284; called by muse, mutect2, varscan2
- LRP1 | c.9433C>T p.R3145C | Missense Mutation (SNP) | VAF 9/42 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99675609, COSV99677603; called by muse, mutect2, varscan2
- LRP1B | c.3377C>T p.S1126L | Missense Mutation (SNP) | VAF 49/194 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV101256072; called by muse, mutect2, varscan2
- LRP2 | c.1078C>A p.Q360K | Missense Mutation (SNP) | VAF 34/195 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV99788109; called by muse, mutect2, varscan2
- LRRC52 | c.212T>C p.M71T | Missense Mutation (SNP) | VAF 95/438 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as COSV99673825; called by muse, mutect2, varscan2
- LUM | c.784T>C p.S262P | Missense Mutation (SNP) | VAF 58/362 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99899007; called by muse, mutect2, varscan2
- LY6K | c.302G>A p.R101Q | Missense Mutation (SNP) | VAF 6/35 reads (17%) | SIFT tolerated (0.57); PolyPhen benign (0.003); catalogued as rs782212141, COSV52832959; called by muse, mutect2
- MAB21L2 | c.323G>A p.R108Q | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT tolerated (0.11); PolyPhen probably damaging (1); catalogued as COSV100462110; called by muse, mutect2, varscan2
- MACC1 | c.167G>A p.R56H | Missense Mutation (SNP) | VAF 52/207 reads (25%) | SIFT tolerated (0.5); PolyPhen benign (0); catalogued as rs202049959; called by muse, mutect2, varscan2
- MACO1 | c.849A>G p.I283M | Missense Mutation (SNP) | VAF 26/170 reads (15%) | SIFT tolerated (0.27); PolyPhen benign (0.078); catalogued as COSV100975141; called by muse, mutect2, varscan2
- MAN1A1 | c.1513G>A p.A505T | Missense Mutation (SNP) | VAF 47/196 reads (24%) | SIFT tolerated (1); PolyPhen probably damaging (1); catalogued as rs766457235, COSV100870632; called by muse, mutect2, varscan2
- MAP2K4 | c.296C>T p.A99V | Missense Mutation (SNP) | VAF 86/359 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.307); catalogued as COSV100796222; called by muse, mutect2, varscan2
- MAP3K21 | c.1091C>T p.P364L | Missense Mutation (SNP) | VAF 175/594 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV100786260; called by muse, varscan2
- MAP4K4 | c.2870A>C p.K957T (on ENST00000347699 / NM_001242559.2; = p.K875T on NM_004834.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 435/1697 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as COSV100154616; called by muse, mutect2, varscan2
- MAP9 | c.604A>G p.S202G | Missense Mutation (SNP) | VAF 40/1216 reads (3%) | SIFT tolerated (0.46); PolyPhen benign (0.116); catalogued as rs1381178930, COSV100250875; called by muse, mutect2
- MAP9 | c.169G>T p.G57C | Missense Mutation (SNP) | VAF 21/127 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.099); catalogued as COSV100250878; called by muse, mutect2, varscan2
- MAPK10 | c.343T>G p.L115V (on ENST00000359221 / NM_001351625.2; = p.L153V on NM_002753.5) | Missense Mutation (SNP) | VAF 124/398 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100174288; called by muse, mutect2, varscan2
- MAPKAPK5 | c.23A>G p.D8G | Missense Mutation (SNP) | VAF 12/82 reads (15%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.025); catalogued as rs773408629, COSV101459644; called by muse, mutect2, varscan2
- MATN2 | c.724T>C p.C242R | Missense Mutation (SNP) | VAF 51/233 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.903); catalogued as COSV99646196; called by muse, mutect2, varscan2
- MBTPS1 | c.2122G>A p.A708T | Missense Mutation (SNP) | VAF 37/170 reads (22%) | SIFT tolerated (0.64); PolyPhen benign (0); catalogued as rs768994789, COSV58570153; called by muse, mutect2, varscan2
- MCM4 | c.2266A>G p.I756V | Missense Mutation (SNP) | VAF 38/103 reads (37%) | SIFT tolerated (0.3); PolyPhen benign (0.003); catalogued as rs1382021959, COSV100031479; called by muse, mutect2, varscan2
- MDH1 | c.484C>T p.R162* | Nonsense Mutation (SNP) | VAF 18/56 reads (32%) | catalogued as rs1183532328, COSV99250985; called by muse, mutect2, varscan2
- MDN1 | c.10147C>T p.R3383W | Missense Mutation (SNP) | VAF 49/155 reads (32%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.791); catalogued as rs770965969, COSV101021232; called by muse, mutect2, varscan2
- MED1 | c.437del p.N146Ifs*24 | Frame Shift Del (DEL) | VAF 25/173 reads (14%) | catalogued as COSV56125174; called by mutect2, pindel, varscan2
- MEF2C | c.1318C>T p.R440W | Missense Mutation (SNP) | VAF 63/220 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as COSV60927625; called by muse, mutect2, varscan2
- MEGF8 | c.1316G>A p.R439Q | Missense Mutation (SNP) | VAF 13/46 reads (28%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.805); catalogued as rs922693299, COSV52078406; called by muse, mutect2, varscan2
- MEGF8 | c.4108C>T p.R1370* (on ENST00000251268 / NM_001271938.2; = p.R1303* on NM_001410.3) | Nonsense Mutation (SNP) | VAF 6/18 reads (33%) | catalogued as rs1195649417, COSV99235903; called by muse, mutect2
- METTL22 | c.853C>T p.Q285* | Nonsense Mutation (SNP) | VAF 9/62 reads (15%) | catalogued as COSV99371674; called by muse, mutect2, varscan2
- MFAP4 | c.280C>T p.R94C | Missense Mutation (SNP) | VAF 11/27 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1160355423, COSV100218880; called by muse, mutect2, varscan2
- MFHAS1 | c.1898G>A p.R633H | Missense Mutation (SNP) | VAF 13/45 reads (29%) | SIFT tolerated (0.55); PolyPhen benign (0.001); catalogued as COSV52284172; called by muse, mutect2, varscan2
- MFSD2B | c.1387G>A p.A463T | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.701); catalogued as rs751215494, COSV57853996; called by muse, mutect2, varscan2
- MGA | c.462dup p.R155Efs*24 | Frame Shift Ins (INS) | VAF 118/461 reads (26%) | catalogued as COSV99580018; called by mutect2, pindel, varscan2
- MICAL2 | c.1750G>T p.A584S | Missense Mutation (SNP) | VAF 23/129 reads (18%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.903); catalogued as COSV99817318; called by muse, mutect2, varscan2
- MKI67 | c.224T>C p.V75A | Missense Mutation (SNP) | VAF 38/132 reads (29%) | SIFT tolerated (1); PolyPhen benign (0.038); catalogued as COSV100896464, COSV64073805; called by muse, mutect2
- MLNR | c.1193C>T p.T398M | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT tolerated (0.06); PolyPhen benign (0.114); catalogued as rs200347707; called by muse, varscan2
- MMP21 | c.145G>A p.D49N | Missense Mutation (SNP) | VAF 12/61 reads (20%) | SIFT tolerated (0.06); PolyPhen benign (0.07); catalogued as rs762663007, COSV64288627; called by muse, mutect2, varscan2
- MON2 | c.5061_5063del p.S1688del | In Frame Del (DEL) | VAF 22/138 reads (16%) | catalogued as rs1565723532; called by pindel, varscan2
- MPP4 | c.295C>T p.R99C | Missense Mutation (SNP) | VAF 111/420 reads (26%) | SIFT tolerated (0.08); PolyPhen benign (0.007); catalogued as rs753283774, COSV59628695; called by muse, mutect2, varscan2
- MS4A1 | c.708del p.E237Nfs*6 | Frame Shift Del (DEL) | VAF 30/74 reads (41%) | catalogued as rs779922206; called by mutect2, varscan2
- MST1R | c.4120C>T p.R1374C | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.003); catalogued as rs772336656, COSV99618550; called by muse, mutect2
- MTHFR | c.1468G>A p.G490R | Missense Mutation (SNP) | VAF 18/51 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as rs760349899, COSV57171655; called by muse, mutect2, varscan2
- MTMR10 | c.133G>A p.V45I | Missense Mutation (SNP) | VAF 27/161 reads (17%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.979); catalogued as rs769982335, COSV58727770; called by muse, mutect2, varscan2
- MTUS2 | c.2237G>A p.C746Y | Missense Mutation (SNP) | VAF 76/415 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as rs1472387074, COSV101462179; called by muse, mutect2, varscan2
- MUC16 | c.36080G>A p.R12027Q | Missense Mutation (SNP) | VAF 105/390 reads (27%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.074); catalogued as rs769222839, COSV67471709; called by muse, mutect2, varscan2
- MX1 | c.793C>T p.R265W | Missense Mutation (SNP) | VAF 53/142 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs1374806050, COSV55818896, COSV99912605; called by muse, mutect2, varscan2
- MYBL1 | c.910G>T p.D304Y | Missense Mutation (SNP) | VAF 38/175 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.885); catalogued as COSV101576528; called by muse, mutect2, varscan2
- MYBPC1 | c.684G>C p.Q228H (on ENST00000550270 / NM_206820.2; = p.Q253H on NM_002465.4) | Missense Mutation (SNP) | VAF 18/100 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.845); catalogued as COSV100637950; called by muse, varscan2
- MYCT1 | c.356G>A p.G119D | Missense Mutation (SNP) | VAF 40/224 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.643); catalogued as rs755298602, COSV100924066; called by muse, mutect2, varscan2
- MYEF2 | c.932C>T p.S311F | Missense Mutation (SNP) | VAF 82/341 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV99981530; called by muse, mutect2, varscan2
- MYH11 | c.4414G>A p.D1472N | Missense Mutation (SNP) | VAF 168/604 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs763594267, COSV100258751; called by muse, mutect2, varscan2
- MYH14 | c.1830G>A p.W610* | Nonsense Mutation (SNP) | VAF 11/29 reads (38%) | catalogued as COSV99222552; called by muse, mutect2, varscan2
- MYH7 | c.5065C>T p.R1689C | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs730880915, COSV62522904; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MYH8 | c.2090G>T p.R697M | Missense Mutation (SNP) | VAF 38/164 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.465); catalogued as COSV101238390; called by muse, mutect2, varscan2
- MYO10 | c.2970G>T p.E990D | Missense Mutation (SNP) | VAF 8/214 reads (4%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.119); catalogued as COSV99945250; called by muse, mutect2
- MYO16 | c.101G>A p.R34H | Missense Mutation (SNP) | VAF 56/195 reads (29%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.997); catalogued as rs1260492120, COSV51781943; called by muse, mutect2, varscan2
- MYO18B | c.5618G>A p.R1873Q | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.034); catalogued as rs765439956, COSV59133694; called by muse, mutect2, varscan2
- MYO3B | c.500_502del p.E167del | In Frame Del (DEL) | VAF 98/347 reads (28%) | catalogued as rs1559305504; called by mutect2, pindel, varscan2
- MYT1L | c.2872G>A p.D958N | Missense Mutation (SNP) | VAF 5/13 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs762411264; called by muse, mutect2, varscan2
- NAA11 | c.445C>T p.R149W | Missense Mutation (SNP) | VAF 25/92 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.836); catalogued as rs781256858, COSV99727331; called by muse, mutect2, varscan2
- NAA15 | c.503C>T p.A168V | Missense Mutation (SNP) | VAF 40/181 reads (22%) | SIFT tolerated (0.16); PolyPhen benign (0.019); catalogued as COSV99649501; called by muse, mutect2, varscan2
- NADK | c.180-2A>G p.X60_splice | Splice Site (SNP) | VAF 8/24 reads (33%) | catalogued as COSV100410837; called by muse, mutect2, varscan2
- NAE1 | c.470G>A p.G157E | Missense Mutation (SNP) | VAF 15/236 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99323094; called by muse, mutect2
- NALCN | c.2939C>T p.S980L | Missense Mutation (SNP) | VAF 43/153 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as rs748664264, COSV51920725; called by muse, mutect2, varscan2
- NAP1L3 | c.964G>T p.V322F | Missense Mutation (SNP) | VAF 36/91 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV100220328, COSV59076623; called by muse, mutect2, varscan2
- NBAS | c.4165A>G p.K1389E | Missense Mutation (SNP) | VAF 399/1743 reads (23%) | SIFT tolerated (0.15); PolyPhen benign (0.236); catalogued as rs767891487, COSV99869166; called by muse, varscan2
- NCAPG | c.2417C>A p.T806K | Missense Mutation (SNP) | VAF 59/200 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99265908; called by muse, mutect2, varscan2
- NCBP1 | c.511T>C p.Y171H | Missense Mutation (SNP) | VAF 111/503 reads (22%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.69); catalogued as rs1247010633, COSV100912586; called by muse, mutect2, varscan2
- NCKAP1L | c.235C>T p.R79C | Missense Mutation (SNP) | VAF 240/552 reads (43%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.83); catalogued as COSV53205016; called by muse, mutect2, varscan2
- NCL | c.615C>A p.D205E | Missense Mutation (SNP) | VAF 19/71 reads (27%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as COSV100502333; called by muse, mutect2, varscan2
- NCOR1 | c.7244A>G p.Q2415R | Missense Mutation (SNP) | VAF 53/254 reads (21%) | SIFT tolerated (0.17); PolyPhen benign (0.142); catalogued as rs1047907822, COSV99249536; called by muse, mutect2, varscan2
- NDUFB2 | c.130T>C p.Y44H | Missense Mutation (SNP) | VAF 297/710 reads (42%) | SIFT deleterious (0.03); PolyPhen benign (0.28); catalogued as COSV99199970; called by muse, mutect2, varscan2
- NEB | c.14840C>T p.S4947L | Missense Mutation (SNP) | VAF 76/499 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.157); catalogued as rs780754459, COSV51269633; called by mutect2, varscan2
- NENF | c.207G>T p.K69N | Missense Mutation (SNP) | VAF 224/820 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); catalogued as COSV100877085, COSV65341481; called by muse, mutect2, varscan2
- NES | c.3473C>A p.P1158H | Missense Mutation (SNP) | VAF 13/37 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.431); catalogued as COSV100957852; called by muse, mutect2, varscan2
- NFXL1 | c.380C>T p.T127M | Missense Mutation (SNP) | VAF 147/531 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.568); catalogued as rs1451919026, COSV100216769; called by muse, mutect2, varscan2
- NFYC | c.641A>G p.Q214R | Missense Mutation (SNP) | VAF 12/26 reads (46%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.107); catalogued as COSV58128536; called by muse, mutect2, varscan2
- NID1 | c.2558G>A p.R853Q | Missense Mutation (SNP) | VAF 19/55 reads (35%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.73); catalogued as rs1168383337, COSV51616605; called by muse, mutect2, varscan2
- NIM1K | c.775del p.V259Cfs*7 | Frame Shift Del (DEL) | VAF 100/465 reads (22%) | catalogued as rs769979471, COSV58143570; called by mutect2, pindel, varscan2
- NLRP1 | c.1748del p.K583Rfs*14 | Frame Shift Del (DEL) | VAF 22/136 reads (16%) | catalogued as COSV52567752; called by mutect2, pindel, varscan2
- NLRP5 | c.1175G>A p.R392H | Missense Mutation (SNP) | VAF 12/45 reads (27%) | SIFT tolerated (0.79); PolyPhen benign (0.001); catalogued as rs770891485, COSV66764352; called by muse, mutect2, varscan2
- NLRP7 | c.283G>A p.G95R | Missense Mutation (SNP) | VAF 44/151 reads (29%) | SIFT tolerated (0.43); PolyPhen benign (0); catalogued as rs139884333; called by muse, varscan2
- NOMO1 | c.833C>T p.S278L | Missense Mutation (SNP) | VAF 65/321 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as rs142296824; called by muse, mutect2, varscan2
- NOTCH2 | c.5996del p.N1999Mfs*32 | Frame Shift Del (DEL) | VAF 99/438 reads (23%) | catalogued as rs1446995271; called by mutect2, pindel, varscan2
- NPSR1 | c.238_240del p.K80del | In Frame Del (DEL) | VAF 119/560 reads (21%) | catalogued as rs752444500; called by pindel, varscan2
- NR2C1 | c.1366A>G p.N456D | Missense Mutation (SNP) | VAF 168/376 reads (45%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.98); catalogued as COSV100280435; called by muse, mutect2, varscan2
- NRXN1 | c.3016G>C p.D1006H | Missense Mutation (SNP) | VAF 789/2722 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100454756, COSV58444999; called by mutect2, varscan2
- NRXN1 | c.1841A>G p.Y614C | Missense Mutation (SNP) | VAF 18/76 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100454760; called by muse, varscan2
- NTN1 | c.1099G>A p.V367I | Missense Mutation (SNP) | VAF 8/19 reads (42%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.856); catalogued as rs1160517048, COSV99432835; called by muse, mutect2, varscan2
- NTSR2 | c.1081G>A p.V361M | Missense Mutation (SNP) | VAF 15/43 reads (35%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as rs369667788; called by muse, mutect2, varscan2
- NUAK1 | c.174G>T p.Q58H | Missense Mutation (SNP) | VAF 6/73 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.062); catalogued as COSV99776927; called by muse, mutect2
- NUB1 | c.990del p.K330Nfs*2 | Frame Shift Del (DEL) | VAF 8/54 reads (15%) | catalogued as rs760102115; called by mutect2, varscan2
- NUP107 | c.133A>G p.T45A | Missense Mutation (SNP) | VAF 177/397 reads (45%) | SIFT tolerated, low confidence (0.72); PolyPhen benign (0); catalogued as COSV57494342; called by muse, mutect2, varscan2
- NUP98 | c.3983del p.N1328Tfs*89 (on ENST00000359171 / NM_001365126.1; = p.N1311Tfs*89 on NM_016320.5 and 4 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 75/307 reads (24%) | catalogued as rs1214420150; called by mutect2, pindel, varscan2
- OGT | c.487C>A p.L163M | Missense Mutation (SNP) | VAF 28/638 reads (4%) | SIFT tolerated (0.06); PolyPhen probably damaging (1); catalogued as COSV101035354; called by muse, mutect2
- OMA1 | c.1462T>C p.S488P | Missense Mutation (SNP) | VAF 434/1556 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.143); catalogued as COSV100678071; called by muse, varscan2
- OR10H4 | c.136A>G p.I46V | Missense Mutation (SNP) | VAF 142/555 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as COSV100437712; called by muse, mutect2, varscan2
- OR12D2 | c.792G>T p.E264D | Missense Mutation (SNP) | VAF 105/330 reads (32%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as COSV101011253, COSV65828062; called by muse, mutect2, varscan2
- OR2B3 | c.256G>T p.G86C | Missense Mutation (SNP) | VAF 18/52 reads (35%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as COSV101013785; called by muse, mutect2, varscan2
- OR2F1 | c.918G>T p.W306C | Missense Mutation (SNP) | VAF 96/299 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.235); catalogued as COSV101231306, COSV67331678; called by muse, mutect2, varscan2
- OR5D13 | c.130A>G p.N44D | Missense Mutation (SNP) | VAF 69/206 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV100686846; called by muse, mutect2, varscan2
- OR5R1 | c.240G>T p.K80N | Missense Mutation (SNP) | VAF 20/91 reads (22%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.999); catalogued as COSV100393413; called by muse, mutect2, varscan2
- OR8D2 | c.934T>C p.*312Rext*? | Nonstop Mutation (SNP) | VAF 17/63 reads (27%) | catalogued as COSV100658977; called by muse, mutect2, varscan2
- ORC1 | c.970G>A p.A324T | Missense Mutation (SNP) | VAF 376/1317 reads (29%) | SIFT tolerated (0.36); PolyPhen benign (0.007); catalogued as COSV100856655; called by muse, mutect2, varscan2
- OSBPL6 | c.483G>C p.L161F | Missense Mutation (SNP) | VAF 76/346 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99507298, COSV99507430; called by muse, mutect2, varscan2
- OTUD4 | c.1370G>A p.R457H (on ENST00000447906 / NM_001366057.1; = p.R392H on NM_001102653.1) | Missense Mutation (SNP) | VAF 176/650 reads (27%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.953); catalogued as rs759518520, COSV101485967; called by muse, varscan2
- PACSIN3 | c.1228C>T p.R410C | Missense Mutation (SNP) | VAF 5/12 reads (42%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.828); catalogued as rs753557964, COSV100096316; called by muse, varscan2
- PAFAH1B1 | c.212A>G p.K71R | Missense Mutation (SNP) | VAF 48/161 reads (30%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as COSV101250379; called by muse, mutect2, varscan2
- PAN3 | c.1318G>A p.A440T | Missense Mutation (SNP) | VAF 153/500 reads (31%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.748); catalogued as rs765586023, COSV56701201; called by muse, mutect2, varscan2
- PATE2 | c.53-2A>G p.X18_splice | Splice Site (SNP) | VAF 147/625 reads (24%) | catalogued as COSV100653447; called by muse, mutect2, varscan2
- PATJ | c.1363T>C p.S455P | Missense Mutation (SNP) | VAF 134/592 reads (23%) | SIFT tolerated (0.16); PolyPhen benign (0.174); catalogued as rs771284772, COSV100334037; called by muse, varscan2
- PCDH1 | c.1376A>C p.Q459P | Missense Mutation (SNP) | VAF 61/296 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); catalogued as COSV99746043; called by muse, mutect2, varscan2
- PCDH19 | c.857G>A p.R286H | Missense Mutation (SNP) | VAF 16/49 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.958); catalogued as COSV55265789; called by muse, mutect2, varscan2
- PCDHA4 | c.2056G>A p.A686T | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.005); catalogued as COSV100793379, COSV63543942; called by muse, varscan2
- PCDHGC3 | c.1330C>T p.R444C | Missense Mutation (SNP) | VAF 27/94 reads (29%) | SIFT tolerated (0.17); PolyPhen benign (0.417); catalogued as COSV52751363; called by muse, mutect2, varscan2
- PCF11 | c.3185G>T p.R1062I | Missense Mutation (SNP) | VAF 25/123 reads (20%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.897); catalogued as COSV53527059; called by muse, mutect2, varscan2
- PCLO | c.13585G>A p.E4529K | Missense Mutation (SNP) | VAF 164/602 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.637); catalogued as COSV100431655, COSV61626344; called by muse, mutect2, varscan2
- PCOLCE2 | c.925G>T p.G309C | Missense Mutation (SNP) | VAF 141/482 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.617); catalogued as COSV99930609; called by muse, mutect2, varscan2
- PDHB | c.445G>A p.G149S | Missense Mutation (SNP) | VAF 6/39 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV100240139; called by muse, mutect2, varscan2
- PDLIM5 | c.989T>C p.L330P | Missense Mutation (SNP) | VAF 15/67 reads (22%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as COSV100523606; called by muse, mutect2, varscan2
- PDS5A | c.3076G>A p.D1026N | Missense Mutation (SNP) | VAF 89/390 reads (23%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.967); catalogued as COSV100337325; called by muse, mutect2, varscan2
- PDZRN3 | c.778G>T p.G260* | Nonsense Mutation (SNP) | VAF 25/141 reads (18%) | catalogued as COSV55208092; called by muse, mutect2, varscan2
- PGBD4 | c.1010C>T p.P337L | Missense Mutation (SNP) | VAF 29/135 reads (21%) | SIFT tolerated (0.68); PolyPhen benign (0.349); catalogued as COSV56626642; called by muse, mutect2, varscan2
- PHF6 | c.119C>T p.A40V | Missense Mutation (SNP) | VAF 32/69 reads (46%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.95); catalogued as COSV100136443, COSV59704164; called by muse, mutect2, varscan2
- PHF7 | c.7A>G p.T3A | Missense Mutation (SNP) | VAF 34/187 reads (18%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.006); catalogued as COSV99963872; called by muse, mutect2, varscan2
- PHTF1 | c.601del p.W201Gfs*12 | Frame Shift Del (DEL) | VAF 72/294 reads (24%) | catalogued as rs1156707888; called by pindel, varscan2
- PIKFYVE | c.5396C>T p.T1799I | Missense Mutation (SNP) | VAF 95/273 reads (35%) | SIFT tolerated (0.2); PolyPhen benign (0.013); catalogued as rs147015179; called by muse, mutect2, varscan2
- PIPOX | c.20T>C p.L7P | Missense Mutation (SNP) | VAF 8/57 reads (14%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.564); catalogued as COSV100037971; called by muse, mutect2, varscan2
- PITX2 | c.827C>T p.T276M (on ENST00000354925 / NM_001204397.1; = p.T283M on NM_000325.6) | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV100146295; called by muse, mutect2, varscan2
- PIWIL2 | c.1273C>T p.R425C | Missense Mutation (SNP) | VAF 313/1111 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as rs368245312; called by muse, mutect2, varscan2
- PKHD1 | c.5551G>A p.D1851N | Missense Mutation (SNP) | VAF 74/258 reads (29%) | SIFT tolerated (0.09); PolyPhen benign (0.01); catalogued as rs867595938, COSV100582837; called by muse, mutect2, varscan2
- PKHD1L1 | c.7271T>A p.L2424H | Missense Mutation (SNP) | VAF 157/640 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.375); catalogued as COSV101006026; called by muse, mutect2, varscan2
- PLA2R1 | c.4304G>A p.R1435Q | Missense Mutation (SNP) | VAF 32/148 reads (22%) | SIFT tolerated (0.39); PolyPhen benign (0.001); catalogued as rs182334014; called by muse, mutect2, varscan2
- PLCD4 | c.1029C>A p.S343R | Missense Mutation (SNP) | VAF 57/216 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.454); catalogued as rs550691262, COSV101346875; called by muse, mutect2, varscan2
- PLEKHO2 | c.1354A>G p.R452G | Missense Mutation (SNP) | VAF 9/44 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100060707; called by muse, mutect2, varscan2
- PLXDC1 | c.499C>T p.R167W | Missense Mutation (SNP) | VAF 36/96 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs748638753, COSV100195264; called by muse, mutect2, varscan2
- PNP | c.611C>T p.A204V | Missense Mutation (SNP) | VAF 47/124 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.158); catalogued as rs1466345881, COSV100828956; called by muse, mutect2, varscan2
- POGZ | c.688G>A p.V230I | Missense Mutation (SNP) | VAF 360/1360 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.972); catalogued as COSV99652679; called by muse, mutect2, varscan2
- POLH | c.500G>A p.R167Q | Missense Mutation (SNP) | VAF 11/48 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.564); catalogued as rs201365711, COSV100947758; called by muse, mutect2, varscan2
- POM121L12 | c.287G>A p.G96D | Missense Mutation (SNP) | VAF 4/13 reads (31%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as COSV68693158; called by muse, mutect2
- POU2F3 | c.377T>C p.L126P | Missense Mutation (SNP) | VAF 41/125 reads (33%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.768); catalogued as COSV99501035; called by muse, mutect2, varscan2
- PPIC | c.428G>A p.G143D | Missense Mutation (SNP) | VAF 4/23 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1217806551, COSV60575464; called by muse, mutect2
- PPM1H | c.678dup p.T227Hfs*12 | Frame Shift Ins (INS) | VAF 7/15 reads (47%) | catalogued as rs776895562; called by mutect2, varscan2
- PPP1R12A | c.2749A>G p.R917G | Missense Mutation (SNP) | VAF 101/479 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.916); catalogued as rs61756420, COSV99700296; called by muse, mutect2, varscan2
- PPP1R32 | c.1254C>A p.S418R | Missense Mutation (SNP) | VAF 16/52 reads (31%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.764); catalogued as COSV100087796, COSV58545891; called by muse, mutect2, varscan2
- PPP1R3A | c.1428del p.N476Kfs*4 | Frame Shift Del (DEL) | VAF 36/184 reads (20%) | catalogued as rs1056475720, COSV52881818; called by mutect2, pindel, varscan2
- PRAG1 | c.2047C>T p.Q683* | Nonsense Mutation (SNP) | VAF 13/56 reads (23%) | catalogued as rs1197723743, COSV100422139; called by muse, mutect2, varscan2
- PRDM2 | c.5038T>C p.Y1680H | Missense Mutation (SNP) | VAF 30/134 reads (22%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.691); catalogued as COSV99341517; called by muse, mutect2, varscan2
- PRDM9 | c.2515C>T p.R839W | Missense Mutation (SNP) | VAF 9/56 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.41); catalogued as rs764241201, COSV57010337, COSV57015844; called by muse, mutect2, varscan2
- PREX1 | c.3062G>A p.C1021Y | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.862); catalogued as COSV64249751; called by muse, varscan2
- PRKCG | c.689A>G p.N230S | Missense Mutation (SNP) | VAF 11/23 reads (48%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as COSV99668926; called by muse, mutect2, varscan2
- PRKD1 | c.761G>C p.G254A | Missense Mutation (SNP) | VAF 91/438 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.178); catalogued as COSV100120127; called by muse, mutect2, varscan2
- PRPF4 | c.13C>T p.R5* | Nonsense Mutation (SNP) | VAF 22/56 reads (39%) | catalogued as COSV65252823; called by muse, mutect2, varscan2
- PRSS22 | c.685G>T p.G229C | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50720859, COSV99361830; called by muse, mutect2
- PRUNE2 | c.4439G>A p.G1480E | Missense Mutation (SNP) | VAF 43/134 reads (32%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs749706692, COSV100944500; called by muse, mutect2, varscan2
- PSEN2 | c.869C>A p.P290H | Missense Mutation (SNP) | VAF 30/171 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100423038; called by muse, mutect2, varscan2
- PTGFR | c.585C>A p.D195E | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT tolerated (0.37); PolyPhen benign (0.103); catalogued as rs1345314797, COSV100882281; called by muse, mutect2, varscan2
- PTPRB | c.550A>G p.T184A | Missense Mutation (SNP) | VAF 56/304 reads (18%) | SIFT tolerated (0.52); PolyPhen benign (0.314); catalogued as COSV99717183, COSV99719399; called by muse, mutect2, varscan2
- PTPRC | c.1883T>C p.M628T | Missense Mutation (SNP) | VAF 134/505 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.118); catalogued as COSV100722567; called by muse, mutect2, varscan2
- PTPRG | c.3088G>T p.G1030* | Nonsense Mutation (SNP) | VAF 56/360 reads (16%) | catalogued as COSV99874596; called by muse, mutect2, varscan2
- PTPRK | c.2741A>C p.N914T (on ENST00000368215 / NM_001291984.2; = p.N915T on NM_002844.4) | Missense Mutation (SNP) | VAF 392/1521 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as COSV63893094; called by mutect2, varscan2
- PTPRR | c.922C>T p.R308* | Nonsense Mutation (SNP) | VAF 596/1294 reads (46%) | catalogued as COSV51729025; called by muse, mutect2, varscan2
- PTPRT | c.4140T>G p.N1380K | Missense Mutation (SNP) | VAF 53/117 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.515); catalogued as COSV100626882; called by muse, mutect2, varscan2
- PTPRT | c.2866C>T p.H956Y | Missense Mutation (SNP) | VAF 72/182 reads (40%) | SIFT deleterious (0.04); PolyPhen benign (0.027); catalogued as COSV61986989; called by muse, mutect2, varscan2
- PZP | c.1031C>A p.S344Y | Missense Mutation (SNP) | VAF 104/540 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.313); catalogued as COSV99737573; called by muse, mutect2, varscan2
- RAG2 | c.1496del p.K499Sfs*4 | Frame Shift Del (DEL) | VAF 89/339 reads (26%) | catalogued as rs1251406873; called by mutect2, pindel, varscan2
- RALGAPA1 | c.4067A>C p.D1356A | Missense Mutation (SNP) | VAF 72/296 reads (24%) | SIFT tolerated (0.24); PolyPhen benign (0.027); catalogued as COSV99354443; called by muse, varscan2
- RALGAPB | c.2609G>T p.G870V | Missense Mutation (SNP) | VAF 380/960 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99485135; called by muse, mutect2, varscan2
- RBAK-RBAKDN | c.559C>T p.R187C | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.001); catalogued as rs773470222, COSV101208252; called by muse, mutect2, varscan2
- RBM6 | c.2280del p.K760Nfs*101 | Frame Shift Del (DEL) | VAF 60/232 reads (26%) | catalogued as rs1559645154; called by mutect2, varscan2
- RCVRN | c.160G>A p.A54T | Missense Mutation (SNP) | VAF 100/451 reads (22%) | SIFT tolerated (0.31); PolyPhen benign (0.006); catalogued as rs139258757; called by muse, mutect2, varscan2
- RECQL | c.1191T>A p.N397K | Missense Mutation (SNP) | VAF 123/354 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV101388968; called by muse, mutect2, varscan2
- RFC3 | c.244del p.I82Lfs*25 | Frame Shift Del (DEL) | VAF 42/127 reads (33%) | catalogued as rs753959887; called by mutect2, varscan2
- RFLNB | c.243G>T p.E81D | Missense Mutation (SNP) | VAF 17/112 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV100225050; called by muse, mutect2, varscan2
- RFX3 | c.2013T>A p.D671E | Missense Mutation (SNP) | VAF 26/87 reads (30%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.551); catalogued as COSV101137811; called by muse, mutect2, varscan2
- RGS3 | c.2588G>T p.S863I (on ENST00000350696 / NM_001282923.2; = p.S582I on NM_130795.4) | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.096); catalogued as rs1388533089, COSV100636703; called by muse, mutect2, varscan2
- RGS9 | c.1730G>A p.R577H | Missense Mutation (SNP) | VAF 16/54 reads (30%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.996); catalogued as rs866147892, COSV52225793, COSV52227907; called by muse, mutect2, varscan2
- RHOA | c.182C>T p.A61V | Missense Mutation (SNP) | VAF 17/44 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV69042372, COSV69043849; called by muse, mutect2, varscan2
- RIMKLB | c.94G>A p.A32T | Missense Mutation (SNP) | VAF 109/606 reads (18%) | SIFT tolerated (0.37); PolyPhen benign (0.045); catalogued as COSV100223866; called by muse, mutect2, varscan2
- RIMS2 | c.4676T>C p.F1559S (on ENST00000666250 / NM_001348490.2; = p.F1130S on NM_014677.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 28/712 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51735868; called by muse, mutect2
- RIOK2 | c.1066C>T p.R356W | Missense Mutation (SNP) | VAF 115/378 reads (30%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as rs1161416386, COSV51611853; called by muse, mutect2, varscan2
- RIPK4 | c.1550G>A p.R517H (on ENST00000352483; = p.R469H on NM_020639.3) | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT tolerated (0.37); PolyPhen possibly damaging (0.586); catalogued as rs1288169822, COSV60190880; called by muse, mutect2, varscan2
- RNF6 | c.1778del p.L593Yfs*2 | Frame Shift Del (DEL) | VAF 71/287 reads (25%) | catalogued as rs1199638878, COSV60419447; called by mutect2, varscan2
- ROBO1 | c.1612G>A p.A538T | Missense Mutation (SNP) | VAF 71/271 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs752516128, COSV101458656; called by muse, mutect2, varscan2
- RRAGB | c.641G>A p.R214H (on ENST00000262850 / NM_016656.4; = p.R186H on NM_006064.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 16/348 reads (5%) | SIFT tolerated (0.12); PolyPhen benign (0.022); catalogued as rs1179560118, COSV99469282; called by muse, mutect2
- RSF1 | c.1733G>A p.R578H | Missense Mutation (SNP) | VAF 32/117 reads (27%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0); catalogued as rs748850046, COSV100407151; called by muse, mutect2, varscan2
- RUNX2 | c.505C>T p.R169W | Missense Mutation (SNP) | VAF 96/345 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.348); catalogued as rs1203066173, COSV100767328; called by muse, mutect2, varscan2
- RYR1 | c.8894G>A p.R2965H | Missense Mutation (SNP) | VAF 42/136 reads (31%) | SIFT tolerated (0.14); PolyPhen benign (0.288); catalogued as COSV62098450; called by muse, mutect2, varscan2
- SALL4 | c.2983dup p.V995Gfs*16 | Frame Shift Ins (INS) | VAF 11/38 reads (29%) | catalogued as rs753320334; called by mutect2, varscan2
- SBK1 | c.703G>T p.D235Y | Missense Mutation (SNP) | VAF 9/23 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59397262; called by muse, mutect2, varscan2
- SCLT1 | c.1328A>G p.Y443C | Missense Mutation (SNP) | VAF 222/842 reads (26%) | SIFT tolerated (0.14); PolyPhen benign (0.097); catalogued as rs750715703, COSV99827980; called by muse, mutect2, varscan2
- SCN7A | c.2409T>A p.D803E | Missense Mutation (SNP) | VAF 256/751 reads (34%) | SIFT tolerated (0.21); PolyPhen benign (0.031); catalogued as COSV69272230; called by muse, mutect2, varscan2
- SCN7A | c.233del p.N78Ifs*4 | Frame Shift Del (DEL) | VAF 43/122 reads (35%) | catalogued as rs764500272; called by mutect2, varscan2
- SDK1 | c.2273C>A p.T758K | Missense Mutation (SNP) | VAF 13/36 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67392225; called by muse, mutect2, varscan2
- SEC14L4 | c.824G>T p.R275M | Missense Mutation (SNP) | VAF 24/103 reads (23%) | SIFT tolerated (0.07); PolyPhen benign (0.019); catalogued as COSV99742918; called by muse, mutect2, varscan2
- SEMA4D | c.388G>A p.A130T | Missense Mutation (SNP) | VAF 26/97 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs1398942351, COSV59396572; called by muse, mutect2, varscan2
- SEMA6D | c.125C>T p.P42L | Missense Mutation (SNP) | VAF 144/576 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs765456604, COSV60379446; called by muse, mutect2, varscan2
- SERPINI2 | c.1052G>A p.G351D | Missense Mutation (SNP) | VAF 36/119 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1303012392, COSV52987865; called by muse, mutect2, varscan2
- SFPQ | c.1462T>C p.Y488H | Missense Mutation (SNP) | VAF 56/166 reads (34%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.837); catalogued as COSV100599407; called by muse, mutect2, varscan2
- SH3BP5L | c.376G>A p.A126T | Missense Mutation (SNP) | VAF 5/10 reads (50%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.986); catalogued as COSV100822000; called by muse, mutect2, varscan2
- SHANK1 | c.2620C>T p.R874C | Missense Mutation (SNP) | VAF 47/169 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.895); catalogued as rs1188839671, COSV53246173; called by muse, varscan2
- SHOC1 | c.931A>G p.M311V | Missense Mutation (SNP) | VAF 57/210 reads (27%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100597555; called by muse, mutect2, varscan2
- SHROOM3 | c.2171G>A p.R724Q | Missense Mutation (SNP) | VAF 4/8 reads (50%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.478); catalogued as COSV56022443; called by mutect2, varscan2
- SIM1 | c.289C>A p.P97T | Missense Mutation (SNP) | VAF 26/121 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.771); catalogued as rs1217153562, COSV99492304; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SIPA1L2 | c.1381C>T p.P461S | Missense Mutation (SNP) | VAF 24/600 reads (4%) | SIFT tolerated (0.11); PolyPhen benign (0.222); catalogued as COSV99478054; called by muse, mutect2
- SLC16A13 | c.1184_1186del p.F395del | In Frame Del (DEL) | VAF 24/136 reads (18%) | catalogued as rs752626452; called by pindel, varscan2
- SLC25A31 | c.449G>A p.R150Q | Missense Mutation (SNP) | VAF 339/1074 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs868692313, COSV55422424; called by muse, mutect2, varscan2
- SLC30A8 | c.92C>A p.P31Q | Missense Mutation (SNP) | VAF 31/99 reads (31%) | SIFT tolerated (0.08); PolyPhen benign (0.073); catalogued as COSV69969419, COSV69969771; called by muse, mutect2, varscan2
- SLC4A1AP | c.872A>G p.Q291R | Missense Mutation (SNP) | VAF 37/132 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.326); catalogued as COSV100389324; called by muse, mutect2, varscan2
- SLC7A2 | c.1553C>T p.A518V (on ENST00000494857 / NM_001370338.1; = p.A557V on NM_003046.6) | Missense Mutation (SNP) | VAF 53/206 reads (26%) | SIFT tolerated (0.52); PolyPhen benign (0.059); catalogued as COSV99134729; called by muse, mutect2, varscan2
- SLC9C2 | c.1837G>T p.G613* | Nonsense Mutation (SNP) | VAF 14/59 reads (24%) | catalogued as COSV62945484; called by muse, mutect2, varscan2
- SLCO6A1 | c.1049G>A p.R350H | Missense Mutation (SNP) | VAF 119/408 reads (29%) | SIFT tolerated (0.22); PolyPhen benign (0.288); catalogued as rs201223529; called by muse, mutect2, varscan2
- SMAD9 | c.283G>A p.V95M | Missense Mutation (SNP) | VAF 15/73 reads (21%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.995); catalogued as COSV63204678; called by muse, mutect2, varscan2
- SMC4 | c.1858G>T p.G620W | Missense Mutation (SNP) | VAF 38/178 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100644020; called by muse, mutect2, varscan2
- SMG7 | c.2545del p.M849* | Frame Shift Del (DEL) | VAF 26/75 reads (35%) | catalogued as rs749889899; called by mutect2, varscan2
- SMPX | c.18G>C p.Q6H | Missense Mutation (SNP) | VAF 26/320 reads (8%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.986); catalogued as COSV101069785, COSV65277733; called by muse, mutect2
- SNAI1 | c.613G>A p.E205K | Missense Mutation (SNP) | VAF 6/43 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV54863674; called by muse, varscan2
- SNAPC5 | c.254C>T p.T85M | Missense Mutation (SNP) | VAF 99/376 reads (26%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0); catalogued as rs144538572, COSV57206339; called by muse, mutect2, varscan2
- SNW1 | c.479C>T p.A160V | Missense Mutation (SNP) | VAF 26/86 reads (30%) | SIFT tolerated (0.08); PolyPhen benign (0.06); catalogued as COSV55052787; called by muse, mutect2, varscan2
- SNX25 | c.1716dup p.V573Sfs*7 | Frame Shift Ins (INS) | VAF 36/208 reads (17%) | catalogued as rs780499770; called by mutect2, varscan2
- SNX25 | c.1913del p.N638Ifs*51 | Frame Shift Del (DEL) | VAF 40/179 reads (22%) | catalogued as rs768873484; called by mutect2, varscan2
- SORBS2 | c.1402G>A p.E468K | Missense Mutation (SNP) | VAF 24/101 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as COSV53010149; called by muse, mutect2, varscan2
- SPATA16 | c.44G>T p.R15M | Missense Mutation (SNP) | VAF 117/373 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.007); catalogued as COSV63531169; called by muse, mutect2, varscan2
- SPHKAP | c.4112C>T p.P1371L | Missense Mutation (SNP) | VAF 38/150 reads (25%) | SIFT tolerated (0.13); PolyPhen benign (0.321); catalogued as rs772667973, COSV100764080; called by muse, mutect2, varscan2
- SPRYD7 | c.172G>A p.A58T | Missense Mutation (SNP) | VAF 72/217 reads (33%) | SIFT tolerated (0.14); PolyPhen benign (0.082); catalogued as rs772902529, COSV62523690; called by muse, mutect2, varscan2
- SPTB | c.2518C>T p.R840C | Missense Mutation (SNP) | VAF 12/43 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs759218961, COSV101072094, COSV67633990; called by muse, mutect2, varscan2
- SRCAP | c.600G>T p.K200N | Missense Mutation (SNP) | VAF 24/68 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.78); catalogued as COSV99350000; called by muse, mutect2, varscan2
- SRP72 | c.1742G>A p.R581Q | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.57); catalogued as rs763555511, COSV100714300; called by mutect2, varscan2
- SRPX | c.930G>A p.W310* | Nonsense Mutation (SNP) | VAF 29/71 reads (41%) | catalogued as COSV100656034; called by muse, mutect2, varscan2
- SRRM1 | c.398A>G p.Q133R | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.85); catalogued as COSV100104533; called by muse, mutect2, varscan2
- SRSF6 | c.392G>A p.R131Q | Missense Mutation (SNP) | VAF 8/138 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as COSV54827297, COSV99719690; called by muse, mutect2
- ST8SIA3 | c.792del p.F264Lfs*8 | Frame Shift Del (DEL) | VAF 4/35 reads (11%) | catalogued as COSV60655405; called by mutect2, pindel
- STAB2 | c.4328G>A p.S1443N | Missense Mutation (SNP) | VAF 29/117 reads (25%) | SIFT tolerated (0.13); PolyPhen benign (0.019); catalogued as COSV101185909; called by muse, mutect2, varscan2
- STAG1 | c.2654C>T p.A885V | Missense Mutation (SNP) | VAF 14/402 reads (3%) | SIFT tolerated (0.09); PolyPhen benign (0.266); catalogued as COSV99365310; called by muse, mutect2
- STAMBPL1 | c.1318G>A p.G440S | Missense Mutation (SNP) | VAF 77/284 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.034); catalogued as COSV100905325; called by muse, mutect2, varscan2
- STAT5B | c.1776-2A>G p.X592_splice | Splice Site (SNP) | VAF 14/185 reads (8%) | catalogued as COSV99510921; called by muse, mutect2
- STXBP5L | c.74G>T p.G25V | Missense Mutation (SNP) | VAF 44/114 reads (39%) | SIFT tolerated (0.08); PolyPhen benign (0.031); catalogued as COSV99873749; called by muse, varscan2
- SUCLA2 | c.1282C>T p.R428W (on ENST00000643023; = p.R407W on NM_003850.3) | Missense Mutation (SNP) | VAF 90/386 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1233249991, CM162763, COSV66222631; called by muse, mutect2, varscan2
- SULT1B1 | c.575del p.L192Cfs*6 | Frame Shift Del (DEL) | VAF 102/555 reads (18%) | catalogued as rs1316574540; called by mutect2, pindel, varscan2
- SYNE1 | c.25241C>T p.T8414M (on ENST00000367255 / NM_182961.4; = p.T8366M on NM_033071.3) | Missense Mutation (SNP) | VAF 520/2058 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.855); catalogued as rs759512753, COSV54946518; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SYT5 | c.860G>A p.G287D | Missense Mutation (SNP) | VAF 99/346 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV62831122; called by muse, mutect2, varscan2
- TAOK1 | c.136C>T p.R46* | Nonsense Mutation (SNP) | VAF 41/596 reads (7%) | catalogued as COSV99913944; called by muse, mutect2
- TAP1 | c.2223G>A p.V741= | Splice Region (SNP) | VAF 6/11 reads (55%) | catalogued as COSV62754738; called by muse, mutect2
- TAS2R38 | c.172C>A p.L58M | Missense Mutation (SNP) | VAF 15/86 reads (17%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.833); catalogued as COSV101516415; called by muse, mutect2, varscan2
- TASOR | c.1834T>C p.Y612H (on ENST00000355628 / NM_001365636.2; = p.Y216H on NM_015224.3) | Missense Mutation (SNP) | VAF 62/265 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100843511; called by muse, mutect2, varscan2
- TBC1D23 | c.1478C>T p.A493V | Missense Mutation (SNP) | VAF 112/420 reads (27%) | SIFT tolerated (0.6); PolyPhen benign (0.292); catalogued as COSV61368494; called by muse, mutect2, varscan2
- TBC1D28 | c.490G>A p.G164R | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT tolerated (0.08); PolyPhen benign (0.019); catalogued as rs372865587, COSV100561038; called by muse, mutect2, varscan2
- TCHH | c.3172C>T p.Q1058* | Nonsense Mutation (SNP) | VAF 55/296 reads (19%) | catalogued as COSV100915010; called by muse, mutect2, varscan2
- TECTA | c.1471C>T p.R491C | Missense Mutation (SNP) | VAF 13/49 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1032030939, CM1310314, COSV50713199; called by muse, mutect2, varscan2
- TEK | c.313C>T p.R105* | Nonsense Mutation (SNP) | VAF 26/207 reads (13%) | catalogued as COSV101193377; called by muse, mutect2, varscan2
- TENM1 | c.3665C>T p.S1222L | Missense Mutation (SNP) | VAF 137/360 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.001); catalogued as rs747368597, COSV64424199; called by muse, mutect2, varscan2
- TENM2 | c.5218C>T p.R1740C (on ENST00000518659 / NM_001122679.2; = p.R1501C on NM_001080428.3) | Missense Mutation (SNP) | VAF 31/153 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs1280634774, COSV69129323; called by muse, mutect2, varscan2
- TEX15 | c.6397T>C p.S2133P (on ENST00000256246; = p.S2516P on NM_001350162.2) | Missense Mutation (SNP) | VAF 22/68 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.984); catalogued as COSV99821246; called by muse, mutect2, varscan2
- TFPI2 | c.217G>A p.A73T | Missense Mutation (SNP) | VAF 5/13 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.96); catalogued as rs751463825, COSV55989782; called by muse, mutect2, varscan2
- TGIF1 | c.82C>T p.Q28* (on ENST00000330513 / NM_001374396.1; = p.Q48* on NM_003244.4) | Nonsense Mutation (SNP) | VAF 8/25 reads (32%) | catalogued as COSV100394820; called by muse, varscan2
- THAP2 | c.122G>A p.R41H | Missense Mutation (SNP) | VAF 23/157 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.071); catalogued as rs183448616, COSV57349426; called by muse, mutect2, varscan2
- THOC1 | c.144del p.K48Nfs*12 | Frame Shift Del (DEL) | VAF 26/86 reads (30%) | catalogued as rs746975641; called by mutect2, varscan2
- THRAP3 | c.301C>T p.R101* | Nonsense Mutation (SNP) | VAF 22/125 reads (18%) | catalogued as COSV63566841; called by muse, mutect2
- TIAM1 | c.3882C>T p.F1294= | Splice Region (SNP) | VAF 114/441 reads (26%) | catalogued as rs567504389, COSV54577078; called by muse, mutect2, varscan2
- TIE1 | c.1382G>A p.R461H | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.964); catalogued as rs750816125, COSV65249726; called by muse, mutect2, varscan2
- TKTL2 | c.1085G>A p.R362H | Missense Mutation (SNP) | VAF 17/76 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.964); catalogued as rs770403160, COSV99761350; called by muse, mutect2, varscan2
- TLCD3B | c.262G>A p.D88N | Missense Mutation (SNP) | VAF 8/16 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1178436191, COSV99662407; called by muse, mutect2, varscan2
- TLK1 | c.1046G>A p.R349H | Missense Mutation (SNP) | VAF 1089/3863 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as COSV62629019; called by muse, mutect2, varscan2
- TMCO3 | c.1709C>T p.T570M | Missense Mutation (SNP) | VAF 43/153 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.854); catalogued as rs142314118; called by muse, mutect2, varscan2
- TMEM131 | c.1394C>T p.A465V | Missense Mutation (SNP) | VAF 20/123 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.883); catalogued as rs1325780555, COSV51786738; called by muse, mutect2, varscan2
- TMEM132B | c.278T>C p.V93A | Missense Mutation (SNP) | VAF 22/89 reads (25%) | SIFT tolerated (0.44); PolyPhen benign (0.001); catalogued as COSV100169505; called by muse, mutect2, varscan2
- TMEM132B | c.2213A>G p.Q738R | Missense Mutation (SNP) | VAF 18/452 reads (4%) | SIFT tolerated (0.44); PolyPhen benign (0.019); catalogued as COSV100169508; called by muse, mutect2
- TMEM176B | c.61A>G p.T21A | Missense Mutation (SNP) | VAF 24/154 reads (16%) | SIFT tolerated (0.17); PolyPhen benign (0.007); catalogued as COSV99133687; called by muse, mutect2, varscan2
- TMPO | c.295del p.T99Lfs*12 | Frame Shift Del (DEL) | VAF 74/186 reads (40%) | catalogued as rs770800449; called by mutect2, varscan2
- TMPRSS15 | c.1451del p.N484Tfs*4 | Frame Shift Del (DEL) | VAF 122/584 reads (21%) | catalogued as COSV99518561; called by mutect2, pindel, varscan2
- TMPRSS6 | c.1507G>T p.G503W | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.401); catalogued as COSV100695708; called by muse, mutect2, varscan2
- TMTC3 | c.2274del p.K758Nfs*31 | Frame Shift Del (DEL) | VAF 69/349 reads (20%) | catalogued as rs1304750530; called by pindel, varscan2*
- TMX1 | c.257C>T p.T86I | Missense Mutation (SNP) | VAF 223/838 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.898); catalogued as COSV100790055; called by muse, mutect2, varscan2
- TNC | c.6218G>A p.R2073Q | Missense Mutation (SNP) | VAF 35/125 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs764464070, COSV100405627; called by muse, mutect2, varscan2
- TNFRSF9 | c.346+2T>C p.X116_splice | Splice Site (SNP) | VAF 25/153 reads (16%) | catalogued as COSV101097236; called by muse, mutect2, varscan2
- TOP1 | c.418C>T p.R140* | Nonsense Mutation (SNP) | VAF 436/1168 reads (37%) | catalogued as COSV100793798; called by muse, mutect2, varscan2
- TOR1A | c.331G>A p.V111I | Missense Mutation (SNP) | VAF 32/173 reads (18%) | SIFT tolerated (0.09); PolyPhen benign (0.133); catalogued as rs755593280, COSV61029362; called by muse, mutect2, varscan2
- TP53BP2 | c.260G>A p.R87H | Missense Mutation (SNP) | VAF 33/116 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs776842497, COSV100636599; called by muse, mutect2, varscan2
- TPX2 | c.4T>C p.S2P | Missense Mutation (SNP) | VAF 126/2310 reads (5%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.812); catalogued as COSV55921034; called by muse, mutect2
- TRAM1L1 | c.779G>A p.G260D | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.978); catalogued as rs1560751500, COSV100162171; called by muse, mutect2
- TRIM46 | c.2152dup p.L718Pfs*28 | Frame Shift Ins (INS) | VAF 9/32 reads (28%) | catalogued as rs1198297200; called by mutect2, pindel, varscan2
- TRPV2 | c.2215C>A p.L739M | Missense Mutation (SNP) | VAF 35/126 reads (28%) | SIFT tolerated (0.11); PolyPhen benign (0.146); catalogued as COSV100641192; called by muse, mutect2, varscan2
- TSFM | c.685C>T p.P229S (on ENST00000323833 / NM_001172696.2; = p.P208S on NM_005726.6) | Missense Mutation (SNP) | VAF 32/168 reads (19%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.661); catalogued as COSV99142337; called by muse, mutect2, varscan2
- TSLP | c.286G>T p.E96* | Nonsense Mutation (SNP) | VAF 32/186 reads (17%) | catalogued as COSV61291672; called by muse, mutect2, varscan2
- TTC3 | c.5436G>T p.Q1812H | Missense Mutation (SNP) | VAF 16/38 reads (42%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.548); catalogued as COSV100695409; called by muse, varscan2
- TTC37 | c.1072G>T p.E358* | Nonsense Mutation (SNP) | VAF 102/375 reads (27%) | catalogued as COSV100706581; called by muse, mutect2, varscan2
- TTI1 | c.2770del p.L924Wfs*37 | Frame Shift Del (DEL) | VAF 18/59 reads (31%) | catalogued as rs760253164; called by mutect2, pindel, varscan2
- TTK | c.1743C>A p.H581Q | Missense Mutation (SNP) | VAF 24/94 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV100036232; called by muse, mutect2, varscan2
- TTLL11 | c.829G>T p.G277C | Missense Mutation (SNP) | VAF 73/289 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100388705; called by muse, mutect2, varscan2
- TTN | c.71164C>T p.R23722C (on ENST00000591111; = p.R16298C on NM_003319.4) | Missense Mutation (SNP) | VAF 16/86 reads (19%) | PolyPhen probably damaging (0.917); catalogued as rs757511354, COSV100607532, COSV59879663, COSV60124163; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TTN | c.61371G>T p.Q20457H (on ENST00000591111; = p.Q13033H on NM_003319.4) | Missense Mutation (SNP) | VAF 12/388 reads (3%) | PolyPhen benign (0.001); catalogued as COSV100610128; called by muse, mutect2
- TTN | c.5889del p.V1964Wfs*14 (on ENST00000591111; = p.V1918Wfs*14 on NM_003319.4) | Frame Shift Del (DEL) | VAF 12/69 reads (17%) | catalogued as rs34700943; called by mutect2, pindel, varscan2
- TUB | c.812G>A p.R271Q (on ENST00000299506 / NM_177972.3; = p.R326Q on NM_003320.4) | Missense Mutation (SNP) | VAF 20/59 reads (34%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.854); catalogued as COSV55109558; called by muse, mutect2, varscan2
- TUBA3E | c.1016G>A p.R339H | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.013); catalogued as rs780831143, COSV56058185; called by muse, mutect2, varscan2
- TUBB2A | c.1282G>A p.A428T | Missense Mutation (SNP) | VAF 48/283 reads (17%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.093); catalogued as COSV61319458; called by muse, mutect2, varscan2
- TULP4 | c.1792C>T p.Q598* | Nonsense Mutation (SNP) | VAF 54/212 reads (25%) | catalogued as COSV100893438; called by muse, mutect2, varscan2
- TWNK | c.727G>A p.A243T | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT tolerated (0.17); PolyPhen benign (0.006); catalogued as rs1400893442, COSV99272344; called by muse, mutect2, varscan2
- UBN2 | c.2506C>T p.H836Y | Missense Mutation (SNP) | VAF 52/226 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.968); catalogued as COSV99943877; called by muse, mutect2, varscan2
- UHRF1BP1L | c.3835C>T p.Q1279* | Nonsense Mutation (SNP) | VAF 104/540 reads (19%) | catalogued as rs961000680, COSV99691519; called by muse, mutect2, varscan2
- UNC13C | c.3861G>T p.W1287C | Missense Mutation (SNP) | VAF 47/282 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV99516232; called by muse, varscan2
- UNC79 | c.4972G>T p.G1658C (on ENST00000393151 / NM_001346218.2; = p.G1481C on NM_020818.5) | Missense Mutation (SNP) | VAF 24/80 reads (30%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.747); catalogued as COSV99827535; called by muse, mutect2, varscan2
- UPF1 | c.854T>C p.V285A | Missense Mutation (SNP) | VAF 8/54 reads (15%) | SIFT tolerated (0.16); PolyPhen benign (0.015); catalogued as rs756721195, COSV99439490; called by mutect2, varscan2
- UPK2 | c.150del p.C51Vfs*10 | Frame Shift Del (DEL) | VAF 6/23 reads (26%) | catalogued as rs750952264; called by mutect2, pindel, varscan2
- UPK3A | c.341C>T p.P114L | Missense Mutation (SNP) | VAF 19/82 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs188696049, COSV99343118; called by muse, mutect2, varscan2
- USP15 | c.489G>T p.K163N | Missense Mutation (SNP) | VAF 34/65 reads (52%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.681); catalogued as COSV99739347; called by muse, mutect2, varscan2
- USP24 | c.2711C>T p.A904V | Missense Mutation (SNP) | VAF 170/630 reads (27%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.956); catalogued as COSV53771989; called by muse, mutect2, varscan2
- USP32 | c.506A>G p.Y169C | Missense Mutation (SNP) | VAF 139/426 reads (33%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as rs962576565, COSV100341893; called by muse, mutect2, varscan2
- USP45 | c.1496G>A p.S499N | Missense Mutation (SNP) | VAF 16/63 reads (25%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.864); catalogued as COSV100569623; called by muse, mutect2, varscan2
- UTP3 | c.1406G>A p.R469H | Missense Mutation (SNP) | VAF 67/221 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs747804289, COSV54660870; called by muse, mutect2, varscan2
- UTP6 | c.202A>T p.I68F | Missense Mutation (SNP) | VAF 85/369 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV99911919; called by muse, mutect2, varscan2
- VCAN | c.8579C>A p.S2860Y | Missense Mutation (SNP) | VAF 7/51 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.401); catalogued as COSV99425555; called by muse, mutect2
- VEPH1 | c.82A>G p.I28V | Missense Mutation (SNP) | VAF 342/1490 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.978); catalogued as COSV100747520; called by muse, mutect2, varscan2
- VLDLR | c.1676C>T p.A559V | Missense Mutation (SNP) | VAF 86/292 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.685); catalogued as COSV101173222; called by muse, varscan2
- VPS13D | c.7829A>G p.D2610G | Missense Mutation (SNP) | VAF 57/314 reads (18%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as COSV99166312; called by muse, mutect2, varscan2
- VPS33A | c.1057A>G p.N353D | Missense Mutation (SNP) | VAF 57/151 reads (38%) | SIFT tolerated (0.61); PolyPhen benign (0.079); catalogued as COSV99931334; called by muse, mutect2, varscan2
- VPS4B | c.110C>A p.A37D | Missense Mutation (SNP) | VAF 65/239 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.626); catalogued as COSV99447890; called by muse, mutect2, varscan2
- VWA2 | c.1997G>T p.G666V | Missense Mutation (SNP) | VAF 19/89 reads (21%) | SIFT tolerated (0.21); PolyPhen benign (0.221); catalogued as COSV100073548; called by muse, mutect2, varscan2
- WDR26 | c.1046G>A p.R349H (on ENST00000414423 / NM_001379403.1; = p.R249H on NM_025160.7) | Missense Mutation (SNP) | VAF 71/330 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.666); catalogued as rs772952060, COSV54355453; called by muse, mutect2, varscan2
- WDR43 | c.1722_1724del p.L575del | In Frame Del (DEL) | VAF 78/357 reads (22%) | catalogued as rs1264002274; called by pindel, varscan2
- WDR45 | c.596C>A p.S199Y (on ENST00000376372 / NM_001029896.2; = p.S200Y on NM_007075.3) | Missense Mutation (SNP) | VAF 4/23 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.148); catalogued as COSV100540238, COSV59875868; called by muse, mutect2, varscan2
- WDR55 | c.1022del p.K341Rfs*8 | Frame Shift Del (DEL) | VAF 6/16 reads (38%) | catalogued as rs746919573; called by mutect2, varscan2
- WDR72 | c.3021A>G p.I1007M | Missense Mutation (SNP) | VAF 220/788 reads (28%) | SIFT tolerated (0.11); PolyPhen benign (0.087); catalogued as COSV100854404, COSV64753225; called by muse, mutect2, varscan2
- WNK1 | c.1316T>C p.V439A | Missense Mutation (SNP) | VAF 159/432 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as COSV100267197; called by muse, mutect2, varscan2
- WNK1 | c.1476_1478del p.E492del | In Frame Del (DEL) | VAF 151/455 reads (33%) | catalogued as rs1402275718; called by pindel, varscan2
- WT1 | c.1478G>T p.R493I | Missense Mutation (SNP) | VAF 33/594 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV100187984; called by muse, mutect2
- XDH | c.3235G>A p.A1079T | Missense Mutation (SNP) | VAF 56/162 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.92); catalogued as rs1331025827, COSV101052183; called by muse, mutect2, varscan2
- XIRP1 | c.3402del p.W1135Gfs*2 | Frame Shift Del (DEL) | VAF 17/68 reads (25%) | catalogued as rs1166941994; called by mutect2, pindel, varscan2
- XKR8 | c.902C>T p.A301V | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs1339161578, COSV100871945; called by muse, mutect2, varscan2
- XYLT2 | c.1584del p.G529Afs*78 | Frame Shift Del (DEL) | VAF 5/20 reads (25%) | catalogued as rs779864368; called by pindel, varscan2
- ZBED1 | c.2041G>A p.V681I | Missense Mutation (SNP) | VAF 31/57 reads (54%) | SIFT tolerated, low confidence (0.62); PolyPhen benign (0); catalogued as rs781624072, COSV58131798; called by muse, mutect2, varscan2
- ZBTB20 | c.1940G>T p.S647I (on ENST00000474710 / NM_001164342.2; = p.S574I on NM_015642.6 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 76/250 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.827); catalogued as COSV100613671; called by muse, mutect2, varscan2
- ZBTB41 | c.1478G>A p.C493Y | Missense Mutation (SNP) | VAF 158/646 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100963070; called by muse, mutect2, varscan2
- ZDBF2 | c.5184del p.K1728Nfs*5 | Frame Shift Del (DEL) | VAF 23/72 reads (32%) | catalogued as rs745875253; called by mutect2, varscan2
- ZER1 | c.2024G>A p.R675Q | Missense Mutation (SNP) | VAF 15/71 reads (21%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.953); catalogued as rs760146636, COSV99401873; called by muse, mutect2, varscan2
- ZKSCAN5 | c.1766G>A p.R589H | Missense Mutation (SNP) | VAF 18/58 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.16); catalogued as rs141273536; called by muse, varscan2
- ZNF19 | c.101C>T p.A34V | Missense Mutation (SNP) | VAF 49/166 reads (30%) | SIFT tolerated (0.12); PolyPhen benign (0.099); catalogued as rs17857322, COSV99867284; called by muse, mutect2, varscan2
- ZNF211 | c.1331G>A p.R444Q (on ENST00000347302 / NM_198855.4; = p.R457Q on NM_006385.5) | Missense Mutation (SNP) | VAF 36/110 reads (33%) | SIFT tolerated (1); PolyPhen benign (0.028); catalogued as rs191091619, COSV53745419; called by muse, mutect2, varscan2
- ZNF236 | c.3422A>G p.Q1141R | Missense Mutation (SNP) | VAF 11/28 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as rs761465193, COSV99470225; called by muse, mutect2, varscan2
- ZNF285 | c.533G>A p.R178H | Missense Mutation (SNP) | VAF 27/89 reads (30%) | SIFT tolerated (0.67); PolyPhen benign (0); catalogued as rs773215916, COSV100449973; called by muse, mutect2, varscan2
- ZNF318 | c.4733A>G p.K1578R | Missense Mutation (SNP) | VAF 25/70 reads (36%) | SIFT tolerated, low confidence (0.43); PolyPhen possibly damaging (0.488); catalogued as COSV100546138; called by mutect2, varscan2
- ZNF337 | c.1900G>T p.G634W | Missense Mutation (SNP) | VAF 119/248 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV99430160; called by muse, mutect2, varscan2
- ZNF385D | c.604C>T p.R202W | Missense Mutation (SNP) | VAF 160/602 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.719); catalogued as rs1034519990, COSV55752967; called by muse, mutect2, varscan2
- ZNF438 | c.2101T>A p.W701R | Missense Mutation (SNP) | VAF 38/131 reads (29%) | SIFT deleterious (0.04); PolyPhen benign (0.042); catalogued as COSV100061770; called by muse, mutect2, varscan2
- ZNF446 | c.694G>A p.G232S | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.87); catalogued as rs1179649890, COSV100236199; called by muse, mutect2, varscan2
- ZNF451 | c.1910G>C p.S637T | Missense Mutation (SNP) | VAF 44/167 reads (26%) | SIFT tolerated (0.31); PolyPhen benign (0.084); catalogued as COSV100674873; called by muse, mutect2, varscan2
- ZNF454 | c.250G>T p.D84Y | Missense Mutation (SNP) | VAF 43/160 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.75); catalogued as COSV100194864; called by muse, mutect2, varscan2
- ZNF474 | c.76C>T p.L26F | Missense Mutation (SNP) | VAF 99/368 reads (27%) | SIFT tolerated (0.1); PolyPhen benign (0.005); catalogued as rs1228133450, COSV56948168; called by muse, mutect2, varscan2
- ZNF551 | c.565G>A p.A189T | Missense Mutation (SNP) | VAF 7/20 reads (35%) | SIFT tolerated (0.3); PolyPhen benign (0.081); catalogued as COSV99989946; called by muse, varscan2
- ZNF557 | c.1185del p.K395Nfs*40 (on ENST00000414706 / NM_001044388.2; = p.K402Nfs*40 on NM_024341.3 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 9/36 reads (25%) | catalogued as rs759839287; called by mutect2, varscan2
- ZNF572 | c.18dup p.L7Tfs*7 | Frame Shift Ins (INS) | VAF 41/216 reads (19%) | catalogued as rs769734933; called by mutect2, varscan2
- ZNF592 | c.137T>C p.I46T | Missense Mutation (SNP) | VAF 37/238 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as rs1313923432, COSV100245830; called by muse, mutect2, varscan2
- ZNF619 | c.581G>A p.G194D | Missense Mutation (SNP) | VAF 12/60 reads (20%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.983); catalogued as COSV59030649; called by muse, mutect2, varscan2
- ZNF687 | c.3460C>T p.R1154C | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.981); catalogued as rs139589523; called by muse, mutect2, varscan2
- ZNF701 | c.894dup p.H299Tfs*12 (on ENST00000301093; = p.H233Tfs*12 on NM_018260.3) | Frame Shift Ins (INS) | VAF 11/42 reads (26%) | catalogued as rs762217868; called by mutect2, varscan2
- ZNF780B | c.1741G>A p.G581R | Missense Mutation (SNP) | VAF 181/798 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs369018278; called by muse, mutect2, varscan2
- ZNF804B | c.1078C>A p.P360T | Missense Mutation (SNP) | VAF 13/147 reads (9%) | SIFT tolerated (0.43); PolyPhen benign (0.039); catalogued as COSV100303519; called by muse, mutect2
- ZSCAN16 | c.765_767del p.R256del | In Frame Del (DEL) | VAF 36/138 reads (26%) | catalogued as rs1337667615; called by mutect2, pindel, varscan2
- ZXDC | c.1451C>A p.P484H | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.862); catalogued as COSV60447213; called by muse, mutect2, varscan2
- ABL2 | c.2508del p.K836Nfs*34 (on ENST00000502732 / NM_007314.4; = p.K821Nfs*34 on NM_005158.5) | Frame Shift Del (DEL) | VAF 15/96 reads (16%) | called by mutect2, pindel, varscan2
- ACADVL | c.1382_1383del p.F461* | Frame Shift Del (DEL) | VAF 15/56 reads (27%) | called by mutect2, pindel, varscan2
- ACVR2A | c.1309_1310del p.K437Efs*19 | Frame Shift Del (DEL) | VAF 184/913 reads (20%) | called by pindel, varscan2*
- ADAM10 | c.659del p.N220Ifs*23 | Frame Shift Del (DEL) | VAF 39/427 reads (9%) | called by mutect2, pindel
- ADGRL2 | c.1791del p.K597Nfs*21 | Frame Shift Del (DEL) | VAF 119/424 reads (28%) | called by mutect2, pindel, varscan2
- AMER1 | c.519del p.F173Lfs*36 | Frame Shift Del (DEL) | VAF 21/57 reads (37%) | called by mutect2, pindel, varscan2
- AMIGO1 | c.13C>T p.R5C | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0); called by muse, mutect2
- ANKRD10 | c.519_520del p.A174Pfs*16 | Frame Shift Del (DEL) | VAF 14/66 reads (21%) | called by pindel, varscan2
- AP3B1 | c.2769del p.K923Nfs*4 | Frame Shift Del (DEL) | VAF 36/180 reads (20%) | called by mutect2, varscan2
- ARID2 | c.1556_1559del p.D519Vfs*9 | Frame Shift Del (DEL) | VAF 529/1389 reads (38%) | called by pindel, varscan2
- ATP1A4 | c.2102del p.P701Lfs*20 | Frame Shift Del (DEL) | VAF 59/249 reads (24%) | called by mutect2, pindel, varscan2
- ATP6V0A2 | c.1045_1046dup | Splice Region (INS) | VAF 49/216 reads (23%) | called by mutect2, varscan2
- ATXN10 | c.1365del p.F455Lfs*10 | Frame Shift Del (DEL) | VAF 65/287 reads (23%) | called by mutect2, pindel, varscan2
- AXIN2 | c.143_144dup p.M49Pfs*28 | Frame Shift Ins (INS) | VAF 6/24 reads (25%) | called by mutect2, varscan2
- B2M | c.43_44del p.L15Ffs*41 | Frame Shift Del (DEL) | VAF 94/241 reads (39%) | called by pindel, varscan2
- BZW1 | c.854del p.N285Tfs*11 | Frame Shift Del (DEL) | VAF 13/63 reads (21%) | called by mutect2, varscan2
- CA13 | c.446del p.L149Yfs*65 | Frame Shift Del (DEL) | VAF 71/203 reads (35%) | called by mutect2, pindel, varscan2
- CALD1 | c.1978del p.S660Afs*12 (on ENST00000361675 / NM_033138.4; = p.S405Afs*12 on NM_004342.7) | Frame Shift Del (DEL) | VAF 210/1046 reads (20%) | called by mutect2, pindel, varscan2
- CCDC102B | c.1259del p.N420Tfs*5 | Frame Shift Del (DEL) | VAF 14/74 reads (19%) | called by mutect2, pindel
- CEP290 | c.2645del p.N882Ifs*10 | Frame Shift Del (DEL) | VAF 49/256 reads (19%) | called by mutect2, pindel, varscan2
- CFAP251 | c.2420G>T p.R807M | Missense Mutation (SNP) | VAF 15/192 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.396); called by muse, mutect2
- CLCN3 | c.931del p.R311Gfs*14 | Frame Shift Del (DEL) | VAF 48/218 reads (22%) | called by mutect2, pindel, varscan2
- CNOT10 | c.1709+3_1709+6del p.X570_splice | Splice Site (DEL) | VAF 110/472 reads (23%) | called by pindel, varscan2
- CRISP1 | c.26del p.L9Wfs*13 | Frame Shift Del (DEL) | VAF 30/169 reads (18%) | called by mutect2, pindel, varscan2
- CSNK1G3 | c.888dup p.E297* | Frame Shift Ins (INS) | VAF 82/314 reads (26%) | called by mutect2, varscan2
- CYFIP1 | c.1553T>C p.V518A | Missense Mutation (SNP) | VAF 11/49 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.003); called by muse, mutect2
- DENND3 | c.928del p.L310Sfs*31 | Frame Shift Del (DEL) | VAF 33/170 reads (19%) | called by mutect2, pindel, varscan2
- DMRTC1 | c.515C>A p.P172H | Missense Mutation (SNP) | VAF 22/140 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); called by muse, varscan2
- DNMBP | c.582del p.P195Qfs*5 | Frame Shift Del (DEL) | VAF 87/392 reads (22%) | called by mutect2, pindel, varscan2
- DOCK5 | c.4713del p.F1571Lfs*19 | Frame Shift Del (DEL) | VAF 59/263 reads (22%) | called by mutect2, pindel, varscan2
337 further variants in this file (84 protein-altering or splice-affecting, 232 silent, 21 other) are not listed here.
